Somatic mutation profile of tumor specimen TCGA-CG-5726-01A (aliquot TCGA-CG-5726-01A-11D-1600-08) from TCGA case TCGA-CG-5726, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IA; Tumor grade: G2; Age at diagnosis: 73.9 years (26,998 days).
Specimen TCGA-CG-5726-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 783b75d6-0122-4db0-85d9-01a6a46af687.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CG-5726-11A (Solid Tissue Normal), aliquot TCGA-CG-5726-11A-01D-1600-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d1ffa0eb-166a-47ff-9f20-8e1b301579d2

The open-access MAF lists 1,491 somatic variants for this specimen: 1,143 protein-altering or splice-affecting, 312 silent, 36 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 718, Silent 312, Frame Shift Del 309, Frame Shift Ins 42, Nonsense Mutation 24, Splice Site 20, Intron 18, In Frame Del 16, Splice Region 13, RNA 5, 3'UTR 5, 3'Flank 4.

Variants (750 of 1,491; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALMS1 | c.11700del p.K3900Nfs*8 | Frame Shift Del (DEL) | VAF 26/87 reads (30%) | catalogued as rs1553421626; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- APC | c.4953_4954del p.S1652Hfs*7 | Frame Shift Del (DEL) | VAF 58/175 reads (33%) | catalogued as rs1554086327; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ATP6V1B1 | c.1155del p.I386Sfs*10 | Frame Shift Del (DEL) | VAF 14/94 reads (15%) | catalogued as rs781969081; ClinVar: pathogenic; called by mutect2, pindel
- CFTR | c.50del p.F17Sfs*8 | Frame Shift Del (DEL) | VAF 75/310 reads (24%) | catalogued as rs397508714, CM135530; ClinVar: not provided / pathogenic; called by mutect2, pindel, varscan2
- CHEK2 | c.735del p.F245Lfs*3 (on ENST00000382580 / NM_001005735.2; = p.F202Lfs*3 on NM_007194.4) | Frame Shift Del (DEL) | VAF 9/31 reads (29%) | catalogued as rs886039609; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel
- CYP19A1 | c.1123C>T p.R375C | Missense Mutation (SNP) | VAF 109/299 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434536, CM950332, COSV53057248; ClinVar: pathogenic; called by muse, mutect2, varscan2
- LARP7 | c.1213del p.T405Qfs*5 | Frame Shift Del (DEL) | VAF 21/47 reads (45%) | catalogued as rs750946801; ClinVar: likely pathogenic; called by mutect2, varscan2
- LRP2 | c.13139del p.P4380Hfs*46 | Frame Shift Del (DEL) | VAF 23/55 reads (42%) | catalogued as rs80338754; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- MAN2B1 | c.2402del p.G801Afs*4 | Frame Shift Del (DEL) | VAF 19/75 reads (25%) | catalogued as rs797044680, CM051105; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- MED13L | c.1690C>T p.R564* | Nonsense Mutation (SNP) | VAF 30/84 reads (36%) | catalogued as rs1555247936, COSV56115983; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NIPBL | c.1808del p.K603Sfs*11 | Frame Shift Del (DEL) | VAF 21/151 reads (14%) | catalogued as rs727503767; ClinVar: pathogenic; called by mutect2, varscan2
- PARK7 | c.189dup p.E64Rfs*5 | Frame Shift Ins (INS) | VAF 48/132 reads (36%) | catalogued as rs759703272; ClinVar: likely pathogenic; called by mutect2, varscan2
- PIGO | c.2191del p.R731Vfs*17 | Frame Shift Del (DEL) | VAF 6/38 reads (16%) | catalogued as rs760848629; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- RAD50 | c.2165del p.K722Rfs*14 | Frame Shift Del (DEL) | VAF 52/139 reads (37%) | catalogued as rs397507178, COSV54758496; ClinVar: pathogenic; called by mutect2, varscan2
- RRM2B | c.362G>A p.R121H | Missense Mutation (SNP) | VAF 38/138 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.683); catalogued as rs267607024, CM094794, COSV52565617; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RYR1 | c.11320del p.A3774Rfs*8 | Frame Shift Del (DEL) | VAF 5/20 reads (25%) | catalogued as rs768698639, CM073325, COSV100614110; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- S100A3 | c.289C>T p.P97S | Missense Mutation (SNP) | VAF 55/131 reads (42%) | hotspot (GDC flag); SIFT tolerated (0.14); PolyPhen benign (0.358); catalogued as rs571596892, COSV62876526, COSV62876899; called by muse, mutect2, varscan2
- SACS | c.262C>T p.R88* | Nonsense Mutation (SNP) | VAF 18/42 reads (43%) | catalogued as rs1555255676, COSV66534636; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SPG11 | c.3075del p.E1026Sfs*12 | Frame Shift Del (DEL) | VAF 40/124 reads (32%) | catalogued as rs312262752; ClinVar: pathogenic; called by mutect2, varscan2
- TGM1 | c.566dup p.S190Qfs*49 | Frame Shift Ins (INS) | VAF 39/144 reads (27%) | catalogued as rs1211601030; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- A2ML1 | c.3884C>A p.P1295H | Missense Mutation (SNP) | VAF 59/155 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55285201; called by muse, mutect2, varscan2
- A4GALT | c.973C>T p.R325W | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as rs767523802, COSV50743989; called by muse, mutect2, varscan2
- AADAC | c.1016C>A p.T339N | Missense Mutation (SNP) | VAF 76/188 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs915018015, COSV51758196; called by muse, mutect2, varscan2
- ABCB10 | c.779T>C p.V260A | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.03); catalogued as COSV60619870; called by muse, mutect2, varscan2
- ABCC4 | c.3759A>T p.K1253N | Missense Mutation (SNP) | VAF 14/274 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.08); catalogued as COSV65309817; called by muse, mutect2
- ABCC6 | c.1303G>A p.V435I | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs775802572, COSV52741392; called by muse, mutect2, varscan2
- ABI2 | c.547A>G p.S183G (on ENST00000295851 / NM_001375719.1; = p.S177G on NM_005759.7 and 35 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV53689950; called by muse, mutect2, varscan2
- ABR | c.1106T>C p.V369A (on ENST00000302538 / NM_021962.5; = p.V332A on NM_001092.5) | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.37); catalogued as COSV52141722; called by muse, mutect2, varscan2
- ABT1 | c.581G>A p.R194H | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV51290657; called by muse, mutect2, varscan2
- AC006059.2 | c.1738G>A p.E580K | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.169); catalogued as rs763844733, COSV59605785; called by muse, mutect2, varscan2
- ACAD10 | c.1258C>T p.R420C | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.12); catalogued as rs575221081, COSV58154089; called by muse, mutect2, varscan2
- ACHE | c.1654C>T p.R552W | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.815); catalogued as rs1355424887, COSV53815171; called by muse, mutect2
- ACTA2 | c.479G>C p.G160A | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as CM092902, COSV56515682; called by muse, mutect2, varscan2
- ACTBL2 | c.85del p.R29Gfs*7 | Frame Shift Del (DEL) | VAF 21/64 reads (33%) | catalogued as COSV101379250; called by mutect2, pindel, varscan2
- ACTL6A | c.947G>A p.G316E | Missense Mutation (SNP) | VAF 111/365 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.752); catalogued as COSV66998640; called by muse, mutect2, varscan2
- ACTR10 | c.420T>A p.D140E | Missense Mutation (SNP) | VAF 199/423 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54297379; called by muse, mutect2, varscan2
- ACVR2A | c.285del p.D96Tfs*54 | Frame Shift Del (DEL) | VAF 82/208 reads (39%) | catalogued as rs1312707585, COSV54026507; called by mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 108/268 reads (40%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAMTS17 | c.2006G>A p.G669D | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51473537; called by muse, mutect2, varscan2
- ADAMTS18 | c.2085del p.F695Lfs*7 | Frame Shift Del (DEL) | VAF 86/218 reads (39%) | catalogued as rs772504358, COSV51414270; called by mutect2, varscan2
- ADAMTS18 | c.707C>A p.S236Y | Missense Mutation (SNP) | VAF 51/166 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV51398993; called by muse, mutect2, varscan2
- ADAMTSL4 | c.1142dup p.E382* | Frame Shift Ins (INS) | VAF 43/105 reads (41%) | catalogued as rs749402444; called by mutect2, pindel, varscan2
- ADAMTSL4 | c.1453C>T p.R485C | Missense Mutation (SNP) | VAF 71/189 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs375355414, COSV54996602; called by muse, mutect2, varscan2
- ADCY6 | c.1717C>T p.R573W | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs754674745, COSV57166312; called by muse, mutect2, varscan2
- ADCY8 | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.98); catalogued as COSV53897028, COSV53914687; called by muse, mutect2, varscan2
- ADGRF1 | c.2689T>C p.S897P | Missense Mutation (SNP) | VAF 68/198 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV51944017; called by muse, varscan2
- ADGRG2 | c.2868T>A p.N956K (on ENST00000379869 / NM_001079858.3; = p.N953K on NM_005756.4) | Missense Mutation (SNP) | VAF 146/179 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61337566; called by muse, mutect2, varscan2
- ADGRL1 | c.1171C>T p.R391C (on ENST00000340736 / NM_001008701.3; = p.R386C on NM_014921.5) | Missense Mutation (SNP) | VAF 81/194 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs138963845; called by muse, mutect2, varscan2
- AEN | c.743T>C p.V248A | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.042); catalogued as COSV60428861; called by muse, mutect2, varscan2
- AFAP1L1 | c.1274T>C p.L425P | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV57043852; called by muse, mutect2
- AFAP1L2 | c.2189G>A p.R730H | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs374605165; called by muse, mutect2, varscan2
- AGRN | c.3003del p.G1002Afs*38 | Frame Shift Del (DEL) | VAF 6/18 reads (33%) | catalogued as rs763573703; called by mutect2, varscan2
- AGRN | c.5866G>A p.V1956M | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as rs773243053, COSV65067783; called by muse, mutect2
- AHNAK2 | c.3175G>A p.A1059T | Missense Mutation (SNP) | VAF 99/226 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs369704618, COSV60908177; called by muse, mutect2, varscan2
- AHNAK2 | c.1976del p.K659Rfs*5 | Frame Shift Del (DEL) | VAF 207/577 reads (36%) | catalogued as rs1178630013; called by mutect2, pindel, varscan2
- AJM1 | c.868T>G p.F290V | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.083); catalogued as COSV56031826; called by muse, mutect2
- AKAP12 | c.2699C>T p.T900M | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.041); catalogued as rs771644564, COSV53570410; called by muse, mutect2, varscan2
- AKAP8 | c.1147C>T p.R383C | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs762942536, COSV54101009; called by muse, mutect2, varscan2
- AL121899.2 | c.1339G>C p.V447L | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.155); catalogued as COSV67349752; called by muse, mutect2, varscan2
- ALDH2 | c.864del p.K289Rfs*122 | Frame Shift Del (DEL) | VAF 29/104 reads (28%) | catalogued as rs771889973, COSV55672572; called by mutect2, pindel, varscan2
- ALG10 | c.904del p.S302Pfs*17 | Frame Shift Del (DEL) | VAF 124/432 reads (29%) | catalogued as rs779782051; called by mutect2, pindel, varscan2
- AMBRA1 | c.3535G>A p.G1179S (on ENST00000458649 / NM_001367468.1; = p.G1089S on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1473555913, COSV54048809; called by muse, mutect2, varscan2
- AMPD3 | c.917G>T p.R306L (on ENST00000396553 / NM_001025389.2; = p.R315L on NM_000480.3) | Missense Mutation (SNP) | VAF 112/254 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67329892, COSV67330075; called by muse, mutect2, varscan2
- AMY2A | c.161G>A p.G54E | Missense Mutation (SNP) | VAF 144/490 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs148925092; called by muse, mutect2, varscan2
- ANAPC5 | c.1799C>T p.A600V | Missense Mutation (SNP) | VAF 53/116 reads (46%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.943); catalogued as rs369898477; called by muse, mutect2, varscan2
- ANGPT2 | c.700del p.I234* | Frame Shift Del (DEL) | VAF 96/412 reads (23%) | catalogued as rs34047276; called by mutect2, varscan2
- ANGPT2 | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 32/163 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.04); catalogued as rs749213090, COSV57334978; called by muse, mutect2, varscan2
- ANK1 | c.116G>A p.R39Q | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.31); catalogued as COSV55873359; called by muse, mutect2, varscan2
- ANK3 | c.4931del p.P1644Lfs*27 | Frame Shift Del (DEL) | VAF 45/148 reads (30%) | catalogued as COSV99780925; called by mutect2, pindel, varscan2
- ANKRD49 | c.208del p.M70Wfs*32 | Frame Shift Del (DEL) | VAF 78/211 reads (37%) | catalogued as rs753570186; called by mutect2, varscan2
- ANKS1A | c.959del p.P320Hfs*25 | Frame Shift Del (DEL) | VAF 92/255 reads (36%) | catalogued as COSV64461548; called by mutect2, pindel, varscan2
- ANKS6 | c.1510dup p.Q504Pfs*11 | Frame Shift Ins (INS) | VAF 8/61 reads (13%) | catalogued as rs1277206086; called by mutect2, pindel, varscan2
- ANO3 | c.591G>A p.E197= | Splice Region (SNP) | VAF 42/118 reads (36%) | catalogued as COSV56781198; called by muse, mutect2, varscan2
- ANO6 | c.1367C>T p.A456V | Missense Mutation (SNP) | VAF 123/348 reads (35%) | SIFT tolerated (0.6); PolyPhen benign (0.023); catalogued as rs1272161801, COSV57657063; called by muse, mutect2, varscan2
- ANTXR1 | c.1438C>T p.R480C | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs370351341, COSV58009335; called by muse, mutect2, varscan2
- ANXA4 | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.04); catalogued as rs376382183; called by mutect2, varscan2
- AOX1 | c.738del p.V247* | Frame Shift Del (DEL) | VAF 78/196 reads (40%) | catalogued as rs1559234318, COSV65981656; called by mutect2, pindel, varscan2
- AOX1 | c.1347del p.F449Lfs*44 | Frame Shift Del (DEL) | VAF 57/167 reads (34%) | catalogued as COSV65981536; called by mutect2, pindel, varscan2
- AP1S1 | c.137T>C p.M46T | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.107); catalogued as COSV61760419; called by muse, mutect2
- AP3B1 | c.220A>G p.K74E | Missense Mutation (SNP) | VAF 21/379 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV54876686, COSV54881937; called by muse, mutect2
- AP5M1 | c.553A>G p.N185D | Missense Mutation (SNP) | VAF 50/159 reads (31%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV55104528; called by muse, mutect2, varscan2
- APBA2 | c.2096G>A p.R699H | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV68788804; called by muse, mutect2, varscan2
- APLP2 | c.941C>T p.A314V | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); catalogued as rs367821777; called by muse, mutect2, varscan2
- APOA1 | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52635328; called by muse, mutect2, varscan2
- APOB | c.9011C>A p.A3004D | Missense Mutation (SNP) | VAF 57/157 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV51923848; called by muse, mutect2, varscan2
- APOL3 | c.856G>A p.E286K (on ENST00000349314 / NM_145640.2; = p.E215K on NM_014349.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 81/188 reads (43%) | SIFT tolerated (0.46); PolyPhen benign (0.023); catalogued as rs748753968, COSV62579074; called by muse, varscan2
- AQR | c.2621G>A p.R874H | Missense Mutation (SNP) | VAF 44/349 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377385189; called by muse, mutect2, varscan2
- ARFGAP3 | c.672+1G>A p.X224_splice | Splice Site (SNP) | VAF 9/32 reads (28%) | catalogued as rs760813352, COSV54310547; called by muse, mutect2, varscan2
- ARID1A | c.1650dup p.Y551Lfs*72 | Frame Shift Ins (INS) | VAF 69/247 reads (28%) | catalogued as rs1415146710; called by mutect2, pindel, varscan2
- ARMT1 | c.1295A>G p.Y432C | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66178346; called by muse, mutect2, varscan2
- ARRDC2 | c.837C>G p.D279E | Missense Mutation (SNP) | VAF 9/139 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as COSV55843540; called by muse, mutect2
- ASB1 | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.963); catalogued as rs760949441, COSV52826260; called by muse, mutect2, varscan2
- ASCC3 | c.489del p.F163Lfs*5 | Frame Shift Del (DEL) | VAF 32/160 reads (20%) | catalogued as rs747570359; called by mutect2, varscan2
- ASIC5 | c.173G>A p.S58N | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.02); catalogued as rs756908926, COSV72232512; called by muse, mutect2, varscan2
- ASMT | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 89/144 reads (62%) | SIFT tolerated (0.38); PolyPhen benign (0.012); catalogued as rs762965870, COSV67109568; called by muse, mutect2, varscan2
- ASPHD1 | c.794G>A p.C265Y | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100435953; called by muse, mutect2, varscan2
- ASPN | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 4/54 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.942); catalogued as COSV65015858; called by muse, mutect2
- ATG13 | c.1189T>C p.F397L (on ENST00000359513 / NM_001346321.1; = p.F360L on NM_014741.4 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/170 reads (19%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.977); catalogued as COSV56317520; called by muse, mutect2, varscan2
- ATL2 | c.575C>A p.A192D | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60050518; called by muse, varscan2
- ATOH1 | c.343A>G p.S115G | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1030719508, COSV100024604; called by muse, mutect2
- ATP1A3 | c.2712T>A p.S904R (on ENST00000545399 / NM_001256214.2; = p.S891R on NM_152296.5) | Missense Mutation (SNP) | VAF 56/193 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV57485134; called by muse, mutect2, varscan2
- ATP2A3 | c.1438C>T p.R480W | Missense Mutation (SNP) | VAF 9/153 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as rs1021554812, COSV59226225; called by muse, mutect2
- ATP4A | c.1427G>A p.G476D | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.452); catalogued as rs1166266636, COSV52865688; called by muse, mutect2, varscan2
- ATP8A1 | c.2471T>G p.L824R | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.33); catalogued as COSV52528995; called by muse, mutect2, varscan2
- ATP8B1 | c.3148A>G p.I1050V | Missense Mutation (SNP) | VAF 9/190 reads (5%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.965); catalogued as COSV52173133; called by muse, mutect2
- ATP8B2 | c.140G>T p.R47M (on ENST00000672630; = p.R14M on NM_001005855.2) | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59244763; called by muse, mutect2, varscan2
- ATP9A | c.1671T>C p.D557= | Splice Region (SNP) | VAF 73/274 reads (27%) | catalogued as COSV58763299; called by muse, mutect2, varscan2
- AUTS2 | c.205C>T p.R69W | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV61382490, COSV61384008; called by muse, mutect2, varscan2
- AZIN1 | c.1236-1G>T p.X412_splice | Splice Site (SNP) | VAF 27/141 reads (19%) | catalogued as COSV100457883; called by muse, varscan2
- B3GALT4 | c.30_32del p.L11del | In Frame Del (DEL) | VAF 20/95 reads (21%) | catalogued as rs758140605; called by mutect2, pindel, varscan2
- B3GNT9 | c.606del p.F202Lfs*3 | Frame Shift Del (DEL) | VAF 8/30 reads (27%) | catalogued as rs760854232; called by pindel, varscan2
- BAG6 | c.2226dup p.T743Yfs*23 (on ENST00000676571; = p.T696Yfs*23 on NM_080702.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 12/36 reads (33%) | catalogued as rs1174704559; called by mutect2, pindel
- BAHCC1 | c.2550del p.G851Afs*123 | Frame Shift Del (DEL) | VAF 14/49 reads (29%) | catalogued as COSV57031019; called by mutect2, pindel, varscan2
- BCL7C | c.191G>A p.G64D | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.207); catalogued as COSV53062797; called by muse, mutect2
- BCL9L | c.3115A>C p.M1039L | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV52682033; called by muse, mutect2, varscan2
- BDP1 | c.938del p.L313* | Frame Shift Del (DEL) | VAF 32/108 reads (30%) | catalogued as rs752427670; called by mutect2, varscan2
- BLNK | c.649C>T p.P217S | Missense Mutation (SNP) | VAF 90/204 reads (44%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV56409033; called by muse, mutect2, varscan2
- BMF | c.404G>A p.R135Q | Missense Mutation (SNP) | VAF 48/331 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.034); catalogued as rs760034128, COSV55018649; called by muse, varscan2
- BMP6 | c.1232C>T p.A411V | Missense Mutation (SNP) | VAF 90/214 reads (42%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.735); catalogued as COSV51660771; called by muse, mutect2, varscan2
- BNIP3 | c.610C>T p.R204C | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.345); catalogued as rs376910597; called by muse, mutect2, varscan2
- BPIFB4 | c.311G>A p.R104Q | Missense Mutation (SNP) | VAF 64/191 reads (34%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.885); catalogued as rs773000957, COSV64950680; called by muse, mutect2, varscan2
- BRAF | c.958G>A p.A320T | Missense Mutation (SNP) | VAF 38/174 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs1461617552, COSV56074414; ClinVar: uncertain significance; called by muse, varscan2
- BRD7 | c.1370A>T p.Y457F | Missense Mutation (SNP) | VAF 61/164 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.062); catalogued as COSV67158292, COSV67160314; called by muse, mutect2, varscan2
- BRD8 | c.2250-3del | Splice Region (DEL) | VAF 26/74 reads (35%) | catalogued as rs749043197; called by mutect2, varscan2
- BTNL3 | c.989T>A p.V330E | Missense Mutation (SNP) | VAF 79/193 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61564374; called by muse, mutect2, varscan2
- C12orf45 | c.472A>G p.I158V | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs780475223, COSV55012451; called by muse, mutect2, varscan2
- C2CD5 | c.1814G>A p.G605D | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.092); catalogued as COSV61722883; called by muse, mutect2
- C7orf50 | c.215del p.K72Rfs*87 | Frame Shift Del (DEL) | VAF 28/71 reads (39%) | catalogued as COSV62475944; called by mutect2, pindel, varscan2
- CA9 | c.1266_1268del p.L423del | In Frame Del (DEL) | VAF 42/146 reads (29%) | catalogued as rs986636531; called by pindel, varscan2
- CACNA1E | c.2813G>A p.R938Q | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs762485881, COSV100706283, COSV62382855; called by muse, mutect2, varscan2
- CACNA1H | c.3035C>T p.A1012V | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61984111; called by muse, mutect2, varscan2
- CACNA2D3 | c.2111T>A p.I704N | Missense Mutation (SNP) | VAF 65/150 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as COSV55515286; called by muse, mutect2, varscan2
- CACNG7 | c.107T>C p.M36T | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.53); PolyPhen benign (0.009); catalogued as COSV55813032; called by muse, mutect2, varscan2
- CACNG7 | c.587C>T p.S196F | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55813042; called by muse, mutect2
- CACTIN | c.910C>T p.R304W | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs551044617, COSV50266721; called by muse, mutect2, varscan2
- CAMTA2 | c.2200C>T p.R734W | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs777690609, COSV61833185; called by muse, mutect2, varscan2
- CAPN11 | c.1022T>C p.V341A | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.473); catalogued as COSV67236177; called by muse, mutect2, varscan2
- CARS1 | c.2003C>T p.A668V | Missense Mutation (SNP) | VAF 28/461 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.1); catalogued as rs141404196; called by muse, mutect2
- CASP5 | c.533del p.N178Ifs*8 | Frame Shift Del (DEL) | VAF 86/232 reads (37%) | catalogued as rs765105588; called by mutect2, varscan2
- CASP7 | c.375del p.A126Lfs*17 | Frame Shift Del (DEL) | VAF 59/196 reads (30%) | catalogued as rs1247046723, COSV61881818; called by mutect2, pindel, varscan2
- CAVIN2 | c.13G>A p.A5T | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.268); catalogued as COSV58424000; called by muse, mutect2, varscan2
- CBLN3 | c.206del p.P69Lfs*35 | Frame Shift Del (DEL) | VAF 10/33 reads (30%) | catalogued as rs1268177561; called by mutect2, pindel, varscan2
- CBX3 | c.42del p.K14Nfs*23 | Frame Shift Del (DEL) | VAF 28/110 reads (25%) | catalogued as COSV61761904; called by mutect2, pindel
- CCDC110 | c.1774dup p.T592Nfs*14 | Frame Shift Ins (INS) | VAF 55/158 reads (35%) | catalogued as rs368765497; called by mutect2, varscan2
- CCDC110 | c.1267C>T p.Q423* | Nonsense Mutation (SNP) | VAF 142/374 reads (38%) | catalogued as COSV56869439; called by muse, mutect2, varscan2
- CCDC158 | c.2665-1G>A p.X889_splice | Splice Site (SNP) | VAF 27/238 reads (11%) | catalogued as COSV66355224; called by muse, mutect2, varscan2
- CCDC178 | c.874del p.M292Wfs*3 | Frame Shift Del (DEL) | VAF 30/150 reads (20%) | catalogued as rs535192849; called by mutect2, varscan2
- CCDC62 | c.2036del p.N679Ifs*18 | Frame Shift Del (DEL) | VAF 108/340 reads (32%) | catalogued as rs1053262354; called by mutect2, pindel, varscan2
- CCDC78 | c.970del p.Q324Kfs*6 | Frame Shift Del (DEL) | VAF 34/116 reads (29%) | catalogued as rs1384164328; called by pindel, varscan2
- CCNI | c.775G>A p.V259I | Missense Mutation (SNP) | VAF 55/145 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.799); catalogued as rs780304847, COSV52959194; called by muse, mutect2, varscan2
- CCT3 | c.947G>T p.R316L | Missense Mutation (SNP) | VAF 89/216 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV55287541; called by muse, mutect2, varscan2
- CD163 | c.764G>T p.G255V | Missense Mutation (SNP) | VAF 11/324 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); catalogued as COSV63129610; called by muse, mutect2
- CD19 | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.137); catalogued as COSV61187800; called by muse, mutect2, varscan2
- CD3E | c.443T>C p.V148A | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); catalogued as COSV62345228; called by muse, mutect2, varscan2
- CDCA2 | c.667G>A p.G223S | Missense Mutation (SNP) | VAF 72/382 reads (19%) | SIFT tolerated (0.76); PolyPhen benign (0.059); catalogued as COSV57944461; called by muse, mutect2, varscan2
- CDH4 | c.1724A>G p.Y575C | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.983); catalogued as COSV64642493; called by muse, mutect2
- CDH5 | c.1009G>A p.V337I | Missense Mutation (SNP) | VAF 121/281 reads (43%) | SIFT tolerated (0.96); PolyPhen benign (0.01); catalogued as rs147523967; called by muse, mutect2, varscan2
- CDH8 | c.1933C>T p.R645W | Missense Mutation (SNP) | VAF 73/170 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767625854, COSV54849328, COSV54870356; called by muse, mutect2, varscan2
- CDHR2 | c.1324G>A p.E442K | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs114930966, COSV56141724; called by muse, varscan2
- CDHR3 | c.1390C>T p.P464S | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as COSV58413920; called by muse, mutect2, varscan2
- CDHR5 | c.461G>A p.R154H | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.276); catalogued as rs980805505, COSV51563888; called by muse, mutect2, varscan2
- CDNF | c.385+2T>C p.X129_splice | Splice Site (SNP) | VAF 100/238 reads (42%) | catalogued as rs768956956, COSV65805608; called by muse, mutect2, varscan2
- CDRT4 | c.289T>A p.S97T | Missense Mutation (SNP) | VAF 28/177 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56464701; called by muse, mutect2, varscan2
- CELSR1 | c.3233C>T p.S1078L | Missense Mutation (SNP) | VAF 56/137 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV53083848; called by muse, mutect2, varscan2
- CEMIP | c.652C>T p.R218C | Missense Mutation (SNP) | VAF 45/298 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1234631188, COSV54988324; called by muse, mutect2, varscan2
- CEP120 | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 43/121 reads (36%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs778932435, COSV60264126; called by muse, mutect2, varscan2
- CEP170 | c.1396A>C p.S466R | Missense Mutation (SNP) | VAF 72/192 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as COSV60506214; called by muse, mutect2, varscan2
- CERT1 | c.1402-3del | Splice Region (DEL) | VAF 18/46 reads (39%) | catalogued as rs768479535; called by mutect2, varscan2
- CFAP53 | c.203A>G p.Q68R | Missense Mutation (SNP) | VAF 91/254 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0.04); catalogued as COSV68351334; called by muse, mutect2, varscan2
- CHD6 | c.1175G>T p.G392V | Missense Mutation (SNP) | VAF 32/157 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as COSV58553988; called by muse, mutect2, varscan2
- CHD6 | c.664C>T p.R222W | Missense Mutation (SNP) | VAF 55/223 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.582); catalogued as COSV58553993; called by muse, mutect2, varscan2
- CHGB | c.1126C>T p.Q376* | Nonsense Mutation (SNP) | VAF 55/224 reads (25%) | catalogued as COSV66759609; called by muse, mutect2, varscan2
- CHPF | c.1654C>T p.R552C | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.86); catalogued as rs763280868, COSV60533561; called by muse, mutect2
- CHPF2 | c.397T>C p.Y133H | Missense Mutation (SNP) | VAF 38/187 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV50389097; called by muse, mutect2, varscan2
- CHRD | c.2519G>A p.R840H | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772596758, COSV52605599; called by muse, mutect2, varscan2
- CHRNA3 | c.715C>T p.R239C | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs61737495, COSV58774072; called by muse, mutect2, varscan2
- CHRNB3 | c.809C>T p.S270L | Missense Mutation (SNP) | VAF 91/512 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753349291, COSV51493271, COSV51497886; called by muse, mutect2, varscan2
- CHST1 | c.746A>G p.D249G | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.937); catalogued as COSV57321800; called by muse, mutect2, varscan2
- CHST12 | c.590G>A p.R197H | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.775); catalogued as COSV51673851; called by muse, mutect2, varscan2
- CHST8 | c.1102C>A p.L368M | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52856381; called by muse, mutect2, varscan2
- CHTF18 | c.2420G>A p.R807H | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.198); catalogued as rs756795078, COSV50210533; called by muse, mutect2, varscan2
- CILP2 | c.986A>G p.N329S | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs369786318; called by muse, mutect2, varscan2
- CLK2 | c.1315C>T p.R439W (on ENST00000368361 / NM_001294339.2; = p.R438W on NM_003993.4) | Missense Mutation (SNP) | VAF 29/218 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as rs1278093582, COSV56943775; called by muse, mutect2, varscan2
- CLK2 | c.1102G>T p.G368C (on ENST00000368361 / NM_001294339.2; = p.G367C on NM_003993.4) | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56943781; called by muse, mutect2, varscan2
- CLK3 | c.1607A>C p.K536T (on ENST00000395066 / NM_001130028.1; = p.K388T on NM_003992.4) | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.243); catalogued as COSV59339142; called by muse, mutect2, varscan2
- CLUAP1 | c.442A>G p.T148A | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV58892645; called by muse, mutect2, varscan2
- CLUH | c.3266G>A p.R1089H (on ENST00000435359; = p.R1128H on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV70927795; called by muse, mutect2, varscan2
- CNTLN | c.3922del p.M1308* | Frame Shift Del (DEL) | VAF 45/253 reads (18%) | catalogued as rs761011518, COSV99078405; called by mutect2, pindel, varscan2
- CNTN1 | c.2179T>C p.W727R | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61636385; called by muse, mutect2, varscan2
- CNTN2 | c.2395G>A p.E799K | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.245); catalogued as rs766215909, COSV59348217; called by muse, mutect2, varscan2
- CNTRL | c.2131C>T p.R711W | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as rs769763623, COSV53043380; called by muse, mutect2, varscan2
- COBLL1 | c.2834del p.L945Cfs*12 (on ENST00000392717; = p.L907Cfs*12 on NM_014900.5) | Frame Shift Del (DEL) | VAF 33/71 reads (46%) | catalogued as rs374805044; called by mutect2, varscan2
- COL1A2 | c.1256C>A p.P419H | Missense Mutation (SNP) | VAF 34/48 reads (71%) | SIFT tolerated (0.07); PolyPhen benign (0.315); catalogued as COSV51953119; called by muse, varscan2
- COL4A2 | c.4226G>T p.R1409M | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.926); catalogued as COSV64624969; called by muse, mutect2, varscan2
- COLEC12 | c.1400G>A p.G467E | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68368717; called by muse, mutect2, varscan2
- COPG1 | c.1075C>T p.R359C | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.346); catalogued as rs747015149, COSV59112488; called by muse, mutect2, varscan2
- CORO2B | c.1159G>T p.G387C | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55950329; called by muse, mutect2, varscan2
- CORT | c.14C>A p.P5H | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as COSV57630013; called by muse, mutect2, varscan2
- CPAMD8 | c.3517G>A p.V1173I (on ENST00000651564; = p.V1126I on NM_015692.5) | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.063); catalogued as rs367994692; called by muse, mutect2, varscan2
- CPED1 | c.2778del p.K926Nfs*6 | Frame Shift Del (DEL) | VAF 67/303 reads (22%) | catalogued as rs777945397; called by mutect2, pindel, varscan2
- CPXM1 | c.1099C>T p.R367W | Missense Mutation (SNP) | VAF 58/211 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1440815722, COSV66044631; called by muse, mutect2, varscan2
- CRACD | c.1382G>A p.R461Q | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.59); PolyPhen benign (0.028); catalogued as rs757082455, COSV51715349; called by muse, mutect2, varscan2
- CRCP | c.47T>C p.V16A | Missense Mutation (SNP) | VAF 36/191 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58534676; called by muse, mutect2, varscan2
- CREB3L3 | c.93C>A p.D31E | Missense Mutation (SNP) | VAF 74/173 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV50173145; called by muse, mutect2, varscan2
- CRHR2 | c.211G>A p.V71I | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs988846628, COSV59263758; called by muse, mutect2, varscan2
- CRMP1 | c.1025C>T p.A342V | Missense Mutation (SNP) | VAF 54/160 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.669); catalogued as rs371310830; called by muse, mutect2, varscan2
- CRYGN | c.544C>A p.L182I | Missense Mutation (SNP) | VAF 10/249 reads (4%) | PolyPhen benign (0.007); catalogued as COSV61563588; called by muse, mutect2
- CSF2RB | c.100C>T p.R34C | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); catalogued as rs376449769; called by muse, mutect2, varscan2
- CSF2RB | c.628G>A p.A210T | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53255629; called by muse, mutect2, varscan2
- CSF3R | c.1404del p.S469Afs*22 | Frame Shift Del (DEL) | VAF 49/158 reads (31%) | catalogued as rs747437399; called by mutect2, pindel, varscan2
- CSMD1 | c.9637G>T p.A3213S (on ENST00000520002; = p.A3212S on NM_033225.6) | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.97); catalogued as COSV59283291; called by muse, mutect2, varscan2
- CSMD1 | c.7805G>A p.R2602Q (on ENST00000520002; = p.R2601Q on NM_033225.6) | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs368353601, COSV100144815; called by muse, mutect2, varscan2
- CSMD3 | c.10920del p.F3640Lfs*61 (on ENST00000297405 / NM_001363185.1; = p.F3471Lfs*61 on NM_052900.3) | Frame Shift Del (DEL) | VAF 40/214 reads (19%) | catalogued as rs766438669; called by mutect2, varscan2
- CSPP1 | c.2221G>A p.A741T (on ENST00000676605; = p.A700T on NM_024790.6) | Missense Mutation (SNP) | VAF 80/596 reads (13%) | SIFT tolerated (0.81); PolyPhen benign (0.01); catalogued as COSV51580337; called by muse, varscan2
- CSRP2 | c.411+2T>C p.X137_splice | Splice Site (SNP) | VAF 63/192 reads (33%) | catalogued as COSV60702120, COSV60702632; called by muse, mutect2, varscan2
- CSTF1 | c.389C>T p.A130V | Missense Mutation (SNP) | VAF 102/390 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.831); catalogued as COSV53857930; called by muse, mutect2, varscan2
- CTC1 | c.2249dup p.G751Rfs*40 | Frame Shift Ins (INS) | VAF 21/85 reads (25%) | catalogued as rs1254586169; called by mutect2, pindel, varscan2
- CTNNA2 | c.2279G>A p.R760H | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1323387262, COSV58135759, COSV58143869; called by muse, mutect2, varscan2
- CWC22 | c.1417G>A p.A473T | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.744); catalogued as COSV55426694; called by muse, mutect2
- CXXC1 | c.373G>T p.G125W | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.585); catalogued as COSV53273243; called by muse, mutect2, varscan2
- CXXC4 | c.896A>G p.N299S | Missense Mutation (SNP) | VAF 51/143 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.491); catalogued as COSV101182336; called by muse, mutect2, varscan2
- CYP2F1 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 96/236 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.448); catalogued as rs757859983, COSV58526684; called by muse, mutect2, varscan2
- CYP4F22 | c.239C>T p.A80V | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.042); catalogued as rs116743462, COSV54106603; called by muse, mutect2, varscan2
- DAGLA | c.2593G>A p.V865I | Missense Mutation (SNP) | VAF 58/117 reads (50%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs781535894, COSV57194184; called by muse, mutect2, varscan2
- DCHS1 | c.1949C>A p.P650H | Missense Mutation (SNP) | VAF 32/185 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV55030773; called by muse, mutect2, varscan2
- DCT | c.233G>A p.R78Q | Missense Mutation (SNP) | VAF 61/150 reads (41%) | SIFT tolerated (0.42); PolyPhen benign (0.03); catalogued as rs901996186, COSV65467485; called by muse, mutect2, varscan2
- DCTD | c.322T>G p.F108V | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV63866701; called by muse, mutect2, varscan2
- DDX17 | c.362del p.K121Sfs*4 | Frame Shift Del (DEL) | VAF 33/95 reads (35%) | catalogued as rs759023106; called by mutect2, varscan2
- DDX19A | c.772C>T p.R258C | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100156382, COSV56358747; called by muse, mutect2, varscan2
- DDX23 | c.1120C>T p.R374C | Missense Mutation (SNP) | VAF 98/247 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.15); catalogued as COSV57281915; called by muse, mutect2, varscan2
- DDX60L | c.1634G>A p.R545Q | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs763258755, COSV52708842; called by muse, mutect2, varscan2
- DEFB118 | c.78del p.K26Nfs*19 | Frame Shift Del (DEL) | VAF 30/106 reads (28%) | catalogued as rs750510475, COSV53620107; called by mutect2, varscan2
- DELE1 | c.538A>T p.R180* | Nonsense Mutation (SNP) | VAF 37/85 reads (44%) | catalogued as COSV52003863; called by muse, mutect2, varscan2
- DHX29 | c.2110-1G>C p.X704_splice | Splice Site (SNP) | VAF 40/117 reads (34%) | catalogued as COSV52416591; called by muse, mutect2, varscan2
- DHX36 | c.1011T>G p.H337Q | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57670980; called by muse, mutect2, varscan2
- DIDO1 | c.1425del p.E476Rfs*4 | Frame Shift Del (DEL) | VAF 90/305 reads (30%) | catalogued as rs762377755; called by mutect2, varscan2
- DIP2B | c.2899C>T p.R967C | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56579044; called by muse, mutect2, varscan2
- DISP3 | c.2263C>T p.R755W | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs764393813, COSV53820716; called by muse, mutect2, varscan2
- DKKL1 | c.602G>A p.R201Q | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs369639830, COSV55561344; called by muse, mutect2
- DLC1 | c.3568A>T p.I1190F (on ENST00000276297 / NM_001348081.2; = p.I753F on NM_006094.5) | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.288); catalogued as COSV52290864; called by muse, mutect2, varscan2
- DLC1 | c.2173A>G p.N725D (on ENST00000276297 / NM_001348081.2; = p.N288D on NM_006094.5) | Missense Mutation (SNP) | VAF 40/190 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.054); catalogued as COSV52290878; called by muse, varscan2
- DLEC1 | c.1924G>A p.V642M | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs201339562, COSV57295362; called by muse, varscan2
- DLG5 | c.4742G>A p.R1581H | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.711); catalogued as rs953419715, COSV64946817; called by muse, mutect2, varscan2
- DMRTB1 | c.545G>A p.R182Q | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.033); catalogued as rs564212081, COSV65112648; called by muse, mutect2, varscan2
- DNAH2 | c.3868C>T p.R1290C | Missense Mutation (SNP) | VAF 132/316 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs774774306, COSV66716539, COSV66720980; called by muse, varscan2
- DNAH3 | c.2500C>T p.R834W | Missense Mutation (SNP) | VAF 135/362 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as rs373647786, COSV54549148; called by muse, mutect2, varscan2
- DNAH9 | c.10204del p.L3402Wfs*9 | Frame Shift Del (DEL) | VAF 57/241 reads (24%) | catalogued as rs1377689288, COSV52350099; called by mutect2, pindel, varscan2
- DNAJB6 | c.506A>G p.H169R | Missense Mutation (SNP) | VAF 102/475 reads (21%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.852); catalogued as COSV51094289; called by muse, mutect2, varscan2
- DNAJC13 | c.1960C>T p.R654C | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs776679061, COSV53445908; called by muse, mutect2, varscan2
- DNAJC2 | c.907C>T p.R303W | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as rs1211418461, COSV50789520; called by muse, varscan2
- DNAJC5 | c.106C>T p.R36W | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs946559411, COSV62670880; called by muse, mutect2, varscan2
- DNMT1 | c.2720T>C p.I907T | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV61576618; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 6/54 reads (11%) | catalogued as rs782552436; called by pindel, varscan2
- DOCK4 | c.1429G>A p.V477M | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.215); catalogued as COSV70314859; called by muse, mutect2, varscan2
- DPH2 | c.163C>T p.P55S | Missense Mutation (SNP) | VAF 20/474 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV52542550; called by muse, mutect2
- DPP7 | c.1411G>A p.E471K | Missense Mutation (SNP) | VAF 28/46 reads (61%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs199703007, COSV65370942; called by muse, mutect2, varscan2
- DRC3 | c.999G>A p.S333= | Splice Region (SNP) | VAF 6/14 reads (43%) | catalogued as rs1459977522, COSV58261707; called by muse, mutect2, varscan2
- DRD2 | c.500C>T p.S167F | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60754379; called by muse, mutect2, varscan2
- DSEL | c.2007dup p.R670Tfs*7 | Frame Shift Ins (INS) | VAF 54/179 reads (30%) | catalogued as rs1568245122; called by mutect2, pindel, varscan2
- DST | c.9622C>A p.P3208T | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.087); catalogued as COSV99760670; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.1060del p.W354Gfs*2 | Frame Shift Del (DEL) | VAF 34/154 reads (22%) | catalogued as rs746928635; called by mutect2, varscan2
- DUSP21 | c.236C>T p.S79L | Missense Mutation (SNP) | VAF 89/104 reads (86%) | SIFT deleterious (0.04); PolyPhen benign (0.383); catalogued as rs867156846, COSV100173619, COSV59133623; called by muse, mutect2, varscan2
- DYRK1B | c.358G>T p.G120C | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55681650; called by muse, varscan2
- DYRK1B | c.301G>A p.V101M | Missense Mutation (SNP) | VAF 46/126 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.607); catalogued as rs760848598, COSV55681915; called by muse, varscan2
- DYRK1B | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as rs766827263, COSV55681924; called by muse, mutect2, varscan2
- ECEL1 | c.1259C>T p.A420V | Missense Mutation (SNP) | VAF 41/80 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.393); catalogued as COSV58811239; called by muse, mutect2, varscan2
- EFCAB7 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 44/160 reads (28%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.04); catalogued as rs767896192, COSV52130371; called by muse, mutect2
- EFL1 | c.2359G>A p.E787K | Missense Mutation (SNP) | VAF 70/198 reads (35%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs777187990, COSV51602832, COSV51608771; called by muse, mutect2, varscan2
- EGFR | c.1591C>T p.R531* | Nonsense Mutation (SNP) | VAF 92/324 reads (28%) | catalogued as COSV51772740; called by muse, mutect2, varscan2
- ENTPD7 | c.263_265del p.V88del | In Frame Del (DEL) | VAF 42/128 reads (33%) | catalogued as rs1203832221; called by pindel, varscan2
- EPHA2 | c.2228G>A p.R743H | Missense Mutation (SNP) | VAF 24/176 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1248077614, COSV64452132; called by muse, mutect2, varscan2
- EPHA8 | c.2753G>A p.R918Q | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.992); catalogued as rs141279306; called by muse, mutect2, varscan2
- EPHB2 | c.1994G>A p.R665Q (on ENST00000400191 / NM_001309193.2; = p.R666Q on NM_004442.7) | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs534341737, COSV101006668, COSV65859934; called by muse, mutect2, varscan2
- EPHX2 | c.1277G>T p.G426V | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV66843942, COSV66846197; called by muse, mutect2, varscan2
- ERBB3 | c.917C>A p.P306H | Missense Mutation (SNP) | VAF 165/428 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57247209, COSV57255329; called by muse, mutect2, varscan2
- ERCC3 | c.2291C>T p.S764L | Missense Mutation (SNP) | VAF 58/150 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as rs189511674, COSV53425649; called by muse, mutect2, varscan2
- ESPL1 | c.3260A>G p.Q1087R | Missense Mutation (SNP) | VAF 10/207 reads (5%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV57757437; called by muse, mutect2
- ESPL1 | c.6049C>T p.R2017W | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54475218; called by muse, mutect2, varscan2
- EXOSC5 | c.569G>A p.R190Q | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs770640185, COSV55370592; called by muse, mutect2
- EXT2 | c.496C>T p.R166C (on ENST00000343631; = p.R199C on NM_000401.3) | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.79); catalogued as rs1000640190, COSV59146999; called by muse, mutect2
- F2 | c.472C>T p.R158C | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768825889, COSV61314776; called by mutect2, varscan2
- FAF1 | c.114+2T>C p.X38_splice | Splice Site (SNP) | VAF 10/114 reads (9%) | catalogued as rs1356274574, COSV65636495; called by muse, mutect2
- FAM151A | c.351del p.T118Lfs*43 | Frame Shift Del (DEL) | VAF 37/99 reads (37%) | catalogued as rs749953492; called by mutect2, pindel, varscan2
- FAM3D | c.261C>T p.R87= | Splice Region (SNP) | VAF 11/34 reads (32%) | catalogued as COSV62557765; called by muse, mutect2, varscan2
- FAM53B | c.809C>T p.P270L | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV55101302; called by muse, mutect2, varscan2
- FAM83F | c.959G>A p.R320Q | Missense Mutation (SNP) | VAF 23/176 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as rs777110834, COSV60999483; called by muse, mutect2, varscan2
- FANCD2 | c.2606-1G>T p.X869_splice | Splice Site (SNP) | VAF 14/128 reads (11%) | catalogued as COSV55033028; called by muse, mutect2
- FASTKD1 | c.715C>T p.R239* | Nonsense Mutation (SNP) | VAF 26/100 reads (26%) | catalogued as rs377757166; called by muse, mutect2, varscan2
- FAT3 | c.8903A>G p.N2968S | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV53077322; called by muse, mutect2, varscan2
- FAT4 | c.1663C>T p.R555W | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs756991867, COSV67881602; called by muse, mutect2, varscan2
- FBLIM1 | c.61C>T p.R21C | Missense Mutation (SNP) | VAF 61/140 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs748856645, COSV60028625; called by muse, mutect2, varscan2
- FBN1 | c.1957_1958dup p.D654Lfs*65 | Frame Shift Ins (INS) | VAF 57/136 reads (42%) | catalogued as COSV57313298; called by mutect2, varscan2
- FBN3 | c.2259del p.G754Afs*23 | Frame Shift Del (DEL) | VAF 23/82 reads (28%) | catalogued as COSV54456788; called by mutect2, pindel, varscan2
- FBXO6 | c.178C>T p.R60* | Nonsense Mutation (SNP) | VAF 34/93 reads (37%) | catalogued as COSV65100395; called by muse, mutect2, varscan2
- FBXW12 | c.979A>G p.I327V | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as COSV56482926; called by muse, mutect2, varscan2
- FCRL3 | c.814del p.R272Gfs*3 | Frame Shift Del (DEL) | VAF 56/153 reads (37%) | catalogued as rs1288807478; called by mutect2, pindel, varscan2
- FCRLB | c.1033G>A p.G345S | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV61059334; called by muse, mutect2, varscan2
- FETUB | c.437del p.K146Rfs*4 | Frame Shift Del (DEL) | VAF 30/163 reads (18%) | catalogued as rs748969702; called by mutect2, varscan2
- FFAR4 | c.1099G>A p.V367I | Missense Mutation (SNP) | VAF 33/222 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1424371388, COSV65159635; called by muse, mutect2, varscan2
- FIGLA | c.563A>G p.H188R | Missense Mutation (SNP) | VAF 22/508 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV60088675; called by muse, mutect2
- FN1 | c.4139C>T p.A1380V | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.28); catalogued as COSV60546823; called by muse, mutect2, varscan2
- FOCAD | c.2024C>A p.P675H | Missense Mutation (SNP) | VAF 102/242 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58093702; called by muse, varscan2
- FOXD4L5 | c.290C>T p.A97V | Missense Mutation (SNP) | VAF 34/168 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.041); catalogued as rs1158415338, COSV101073055; called by muse, mutect2, varscan2
- FOXP3 | c.895C>T p.R299W | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.296); catalogued as rs200928046, COSV66050869; ClinVar: likely benign; called by muse, mutect2, varscan2
- FOXS1 | c.379G>A p.A127T | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs773926481, COSV54064940; called by muse, mutect2
- FRMD4A | c.3014del p.P1005Qfs*8 | Frame Shift Del (DEL) | VAF 91/164 reads (55%) | catalogued as rs752538869; called by mutect2, pindel, varscan2
- FRMPD4 | c.1555A>G p.R519G | Missense Mutation (SNP) | VAF 132/181 reads (73%) | SIFT deleterious (0.01); PolyPhen benign (0.212); catalogued as rs1428654411, COSV66211448; called by muse, mutect2, varscan2
- FSHR | c.407C>A p.P136Q | Missense Mutation (SNP) | VAF 25/195 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58617787; called by muse, mutect2, varscan2
- FSIP2 | c.18724C>A p.P6242T | Missense Mutation (SNP) | VAF 58/136 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100556765; called by muse, mutect2, varscan2
- FSTL5 | c.772A>G p.T258A | Missense Mutation (SNP) | VAF 45/106 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.356); catalogued as COSV60182246; called by muse, mutect2, varscan2
- FUBP1 | c.1370C>A p.P457H | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV53926538; called by muse, mutect2, varscan2
- FUBP3 | c.304C>T p.R102W | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368399810; called by muse, mutect2, varscan2
- FZD2 | c.1381C>T p.R461C | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59528128; called by muse, mutect2, varscan2
- FZD5 | c.213G>A p.W71* | Nonsense Mutation (SNP) | VAF 6/34 reads (18%) | catalogued as COSV54942882; called by muse, varscan2
- FZD5 | c.205C>T p.Q69* | Nonsense Mutation (SNP) | VAF 5/31 reads (16%) | catalogued as COSV54942894; called by muse, varscan2
- G3BP1 | c.1034G>A p.G345D | Missense Mutation (SNP) | VAF 14/198 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV62365533; called by muse, mutect2
- GAA | c.2330C>T p.T777M | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.223); catalogued as rs746779016, COSV56406914; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GABARAPL1 | c.284A>G p.Y95C | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56770417; called by muse, mutect2, varscan2
- GABBR1 | c.1721del p.P574Qfs*32 | Frame Shift Del (DEL) | VAF 8/68 reads (12%) | catalogued as rs777471402; called by mutect2, pindel
- GABRG2 | c.519G>A p.W173* | Nonsense Mutation (SNP) | VAF 10/202 reads (5%) | catalogued as COSV62715583; called by muse, mutect2
- GAL3ST1 | c.1018C>T p.R340C | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as rs1372848132, COSV58891905; called by muse, mutect2, varscan2
- GALNT17 | c.158C>T p.A53V | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV61148446; called by muse, mutect2, varscan2
- GALNT18 | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT tolerated (0.7); PolyPhen benign (0.006); catalogued as COSV57144148; called by muse, mutect2
- GALNT9 | c.1195C>T p.R399C (on ENST00000328957 / NM_001122636.2; = p.R33C on NM_021808.3) | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.409); catalogued as rs758686830, COSV61096039; called by muse, mutect2, varscan2
- GALNTL6 | c.929C>T p.P310L | Missense Mutation (SNP) | VAF 158/420 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1383578557, COSV72489452; called by muse, varscan2
- GARRE1 | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.994); catalogued as rs764020643, COSV55096667, COSV55097870; called by muse, mutect2, varscan2
- GBA | c.434A>G p.K145R | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV59168982; called by muse, mutect2, varscan2
- GBP3 | c.856G>A p.V286I | Missense Mutation (SNP) | VAF 76/239 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.082); catalogued as COSV52517491; called by muse, mutect2
- GDF6 | c.1055T>C p.L352P | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.161); catalogued as COSV54622920; called by muse, mutect2
- GFOD1 | c.940C>T p.R314C | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1250234301, COSV64954282; called by muse, mutect2, varscan2
- GFUS | c.748G>A p.V250I | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as COSV55305963; called by muse, mutect2, varscan2
- GFUS | c.271G>A p.V91M | Missense Mutation (SNP) | VAF 39/169 reads (23%) | SIFT tolerated (0.59); PolyPhen benign (0.025); catalogued as rs1480852225, COSV71254160; called by muse, mutect2, varscan2
- GIMAP1 | c.616G>T p.G206W | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as rs1353705507, COSV56187171; called by muse, mutect2
- GLI1 | c.941G>A p.R314H | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373249560, COSV57364723; called by muse, mutect2, varscan2
- GLS2 | c.1177A>G p.M393V | Missense Mutation (SNP) | VAF 48/152 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57665206; called by muse, mutect2, varscan2
- GMEB2 | c.865G>T p.G289C | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56605757, COSV99823467; called by muse, mutect2, varscan2
- GMIP | c.2585G>A p.R862H | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs748790587, COSV52554331; called by muse, mutect2, varscan2
- GNAS | c.1006C>T p.R336W | Missense Mutation (SNP) | VAF 16/210 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.385); catalogued as CM013736, COSV55671184; called by muse, mutect2
- GNB1L | c.135G>T p.Q45H | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.748); catalogued as COSV61547737; called by muse, mutect2, varscan2
- GOLGA4 | c.4098del p.V1367Lfs*10 | Frame Shift Del (DEL) | VAF 30/66 reads (45%) | catalogued as rs768760517; called by mutect2, varscan2
- GOLGB1 | c.9229C>T p.R3077C | Missense Mutation (SNP) | VAF 10/221 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.43); catalogued as rs1195154513, COSV61461905; called by muse, mutect2
- GOPC | c.677G>A p.R226Q | Missense Mutation (SNP) | VAF 118/285 reads (41%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as rs377569741; called by muse, mutect2, varscan2
- GPC1 | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.3); catalogued as rs557977354, COSV50862690; called by muse, mutect2, varscan2
- GPLD1 | c.2270G>A p.R757Q | Missense Mutation (SNP) | VAF 89/197 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs766133257, COSV57754068; called by muse, mutect2, varscan2
- GPLD1 | c.2161G>A p.V721I | Missense Mutation (SNP) | VAF 45/146 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs748536679, COSV57754083; called by muse, mutect2, varscan2
- GPR107 | c.1025C>T p.A342V | Missense Mutation (SNP) | VAF 116/340 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs1389348371, COSV61277248; called by muse, mutect2, varscan2
- GPR174 | c.427C>A p.L143M | Missense Mutation (SNP) | VAF 123/161 reads (76%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.873); catalogued as COSV52131577; called by muse, mutect2, varscan2
- GPR37L1 | c.398T>C p.I133T | Missense Mutation (SNP) | VAF 47/117 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as rs1203606918, COSV66161913; called by muse, varscan2
- GRHL1 | c.1280G>A p.R427Q | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs548450490, COSV61406480, COSV61411073; called by muse, mutect2, varscan2
- GRIA2 | c.2003A>G p.Y668C | Missense Mutation (SNP) | VAF 49/311 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52382840; called by muse, mutect2, varscan2
- GRIK2 | c.2546del p.N849Tfs*14 | Frame Shift Del (DEL) | VAF 82/208 reads (39%) | catalogued as rs760757380; called by mutect2, varscan2
- GRK2 | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781246400, COSV57950445; called by muse, mutect2, varscan2
- GRK7 | c.606T>G p.F202L | Missense Mutation (SNP) | VAF 64/160 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs780171476, COSV53821613, COSV53823667; called by muse, mutect2, varscan2
- GRM5 | c.1036C>T p.P346S | Missense Mutation (SNP) | VAF 60/146 reads (41%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV59591675, COSV59598882; called by muse, mutect2, varscan2
- GRM8 | c.565T>G p.Y189D | Missense Mutation (SNP) | VAF 69/127 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58803141; called by muse, mutect2, varscan2
- GSE1 | c.335del p.P112Lfs*13 | Frame Shift Del (DEL) | VAF 10/92 reads (11%) | catalogued as rs949717861; called by mutect2, varscan2
- GZF1 | c.1217G>A p.R406Q | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.375); catalogued as COSV57634797; called by muse, mutect2, varscan2
- H1-5 | c.67_69del p.K23del | In Frame Del (DEL) | VAF 36/90 reads (40%) | catalogued as rs1463409355; called by pindel, varscan2
- H6PD | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.079); catalogued as COSV66230244; called by muse, mutect2, varscan2
- HAUS6 | c.1588del p.S530Vfs*12 | Frame Shift Del (DEL) | VAF 134/320 reads (42%) | catalogued as rs34558496; called by mutect2, varscan2
- HCFC1 | c.5980G>A p.A1994T | Missense Mutation (SNP) | VAF 47/61 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV60069531; called by muse, mutect2, varscan2
- HECTD3 | c.491A>G p.Q164R | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.901); catalogued as rs753154497, COSV55799019; called by muse, mutect2
- HECW1 | c.760A>G p.K254E | Missense Mutation (SNP) | VAF 37/148 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.119); catalogued as rs1403535264, COSV101223084, COSV67822202; called by muse, mutect2, varscan2
- HERC2 | c.7864T>A p.Y2622N | Missense Mutation (SNP) | VAF 79/214 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55308160; called by muse, mutect2, varscan2
- HERC4 | c.691T>C p.Y231H | Missense Mutation (SNP) | VAF 53/135 reads (39%) | SIFT tolerated (0.54); PolyPhen benign (0.315); catalogued as COSV53268558, COSV53268618; called by muse, mutect2, varscan2
- HERPUD2 | c.1172C>T p.T391I | Missense Mutation (SNP) | VAF 77/283 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs1466868481, COSV60943919; called by muse, mutect2, varscan2
- HGF | c.747-1G>A p.X249_splice | Splice Site (SNP) | VAF 8/128 reads (6%) | catalogued as COSV55945617; called by muse, mutect2
- HGFAC | c.1362del p.R455Gfs*19 | Frame Shift Del (DEL) | VAF 10/90 reads (11%) | catalogued as rs761929917; called by mutect2, pindel, varscan2
- HIPK1 | c.3565C>T p.R1189* (on ENST00000369558 / NM_001369806.1; = p.R795* on NM_181358.2) | Nonsense Mutation (SNP) | VAF 109/267 reads (41%) | catalogued as rs758110661, COSV61246071; called by muse, mutect2, varscan2
- HK2 | c.2104C>T p.R702W | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1359182202, COSV51873333; called by muse, varscan2
- HLA-B | c.709A>T p.I237F | Missense Mutation (SNP) | VAF 22/213 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.773); catalogued as COSV69520447; called by muse, mutect2, varscan2
- HMCN1 | c.5237T>C p.V1746A | Missense Mutation (SNP) | VAF 34/257 reads (13%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.991); catalogued as COSV54878447; called by muse, mutect2, varscan2
- HNRNPF | c.751G>A p.D251N | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV61560504, COSV61560655; called by muse, mutect2, varscan2
- HNRNPK | c.1102G>A p.G368R | Missense Mutation (SNP) | VAF 21/170 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.021); catalogued as rs1443603465, COSV61088291; called by muse, mutect2, varscan2
- HRH2 | c.380C>A p.P127H | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.139); catalogued as COSV51572892; called by muse, mutect2, varscan2
- HRH3 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.345); catalogued as COSV58047563; called by muse, mutect2, varscan2
- HSF5 | c.1554C>A p.N518K | Missense Mutation (SNP) | VAF 160/435 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV60415254; called by muse, mutect2, varscan2
- HSPA1L | c.445C>T p.P149S | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65148658; called by muse, mutect2, varscan2
- HTT | c.4733T>C p.L1578P | Missense Mutation (SNP) | VAF 32/188 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61857609; called by muse, mutect2, varscan2
- HYAL3 | c.1024T>G p.L342V | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60186378; called by muse, mutect2, varscan2
- IDE | c.110del p.K37Rfs*6 | Frame Shift Del (DEL) | VAF 26/156 reads (17%) | catalogued as rs1307048524; called by mutect2, varscan2
- IGF2R | c.3949del p.D1317Tfs*27 | Frame Shift Del (DEL) | VAF 98/234 reads (42%) | catalogued as rs760021495; called by mutect2, varscan2
- IGHM | c.667C>T p.R223W | Missense Mutation (SNP) | VAF 66/190 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as rs782103685; called by muse, mutect2, varscan2
- IL13RA2 | c.1007T>C p.L336P | Missense Mutation (SNP) | VAF 7/127 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0.017); catalogued as COSV54563984; called by muse, mutect2
- IMPG1 | c.151dup p.M51Nfs*29 | Frame Shift Ins (INS) | VAF 99/358 reads (28%) | catalogued as rs761247695; called by mutect2, pindel, varscan2
- INCENP | c.563C>A p.S188Y | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.467); catalogued as COSV53913317; called by muse, mutect2, varscan2
- INF2 | c.2485G>A p.A829T | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.99); catalogued as COSV53029802; called by muse, mutect2, varscan2
- INKA2 | c.559del p.A187Hfs*20 | Frame Shift Del (DEL) | VAF 31/110 reads (28%) | catalogued as rs751997684, COSV61878369; called by mutect2, varscan2
- INTS1 | c.890C>T p.T297M | Missense Mutation (SNP) | VAF 25/245 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.444); catalogued as rs747608555, COSV67176389; called by muse, mutect2, varscan2
- INTS3 | c.1229T>C p.M410T | Missense Mutation (SNP) | VAF 88/258 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as COSV59675229; called by muse, mutect2, varscan2
- IQCE | c.619G>A p.D207N | Missense Mutation (SNP) | VAF 104/167 reads (62%) | SIFT tolerated (0.09); PolyPhen benign (0.222); catalogued as rs764467415, COSV100383823, COSV58076567; called by muse, mutect2, varscan2
- IRF2 | c.321G>T p.R107S | Missense Mutation (SNP) | VAF 71/181 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV66928563; called by muse, mutect2, varscan2
- IRS1 | c.1066G>A p.A356T | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT tolerated (0.7); PolyPhen benign (0.015); catalogued as rs773817315, COSV59333601, COSV59335611; called by muse, varscan2
- IRX6 | c.1274C>T p.A425V | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV51859171; called by muse, mutect2, varscan2
- ISG20L2 | c.865del p.L289Sfs*15 | Frame Shift Del (DEL) | VAF 46/141 reads (33%) | catalogued as rs761558950, COSV57459436; called by mutect2, varscan2
- ISLR | c.196C>A p.P66T | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT tolerated (0.56); PolyPhen benign (0.113); catalogued as COSV51433032; called by muse, varscan2
- ISM1 | c.1205C>T p.T402M | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.95); catalogued as rs1183784591, COSV52602652; called by muse, mutect2, varscan2
- ITIH5 | c.1186C>T p.R396W | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs185691581, COSV53660238; called by muse, mutect2, varscan2
- ITLN1 | c.470C>A p.P157H | Missense Mutation (SNP) | VAF 52/170 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58273885; called by muse, mutect2, varscan2
- ITPRIPL1 | c.604C>T p.R202W (on ENST00000439118 / NM_001008949.3; = p.R210W on NM_178495.6) | Missense Mutation (SNP) | VAF 69/174 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs746251533, COSV63152637; called by muse, mutect2, varscan2
- JAML | c.722T>A p.L241Q (on ENST00000356289 / NM_001098526.2; = p.L231Q on NM_153206.3) | Missense Mutation (SNP) | VAF 196/479 reads (41%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV52626410; called by muse, varscan2
- JAML | c.605T>A p.F202Y (on ENST00000356289 / NM_001098526.2; = p.F192Y on NM_153206.3) | Missense Mutation (SNP) | VAF 121/309 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV52626424; called by muse, varscan2
- JMJD1C | c.7306C>T p.R2436C | Missense Mutation (SNP) | VAF 62/175 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59512865; called by muse, mutect2, varscan2
- JUN | c.401C>A p.A134E | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.083); catalogued as COSV64664173; called by muse, mutect2, varscan2
- KANK2 | c.1051G>A p.A351T | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.199); catalogued as rs745831416, COSV100763163, COSV62006498; called by mutect2, varscan2
- KANK4 | c.134A>G p.D45G | Missense Mutation (SNP) | VAF 13/231 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62985467; called by muse, mutect2
- KAT6B | c.5809G>A p.A1937T | Missense Mutation (SNP) | VAF 63/175 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.235); catalogued as COSV54742409; called by muse, varscan2
- KCNA2 | c.203A>T p.Y68F | Missense Mutation (SNP) | VAF 75/210 reads (36%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.999); catalogued as COSV60369154; called by muse, mutect2, varscan2
- KCNA3 | c.1132T>C p.S378P | Missense Mutation (SNP) | VAF 57/157 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63900994; called by muse, varscan2
- KCNA3 | c.1070C>T p.A357V | Missense Mutation (SNP) | VAF 64/151 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as COSV63900998; called by muse, varscan2
- KCNH6 | c.2209T>C p.F737L | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT tolerated (0.66); PolyPhen benign (0.028); catalogued as COSV59000840; called by muse, mutect2, varscan2
- KCNJ2 | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 91/259 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.311); catalogued as COSV54660170; called by muse, mutect2, varscan2
- KCNJ3 | c.796T>C p.S266P | Missense Mutation (SNP) | VAF 47/163 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV54531542; called by muse, mutect2, varscan2
- KCNK9 | c.1120G>A p.V374I | Missense Mutation (SNP) | VAF 55/327 reads (17%) | SIFT tolerated (0.77); PolyPhen benign (0.006); catalogued as rs149047706; called by muse, mutect2, varscan2
- KCNK9 | c.911C>T p.S304L | Missense Mutation (SNP) | VAF 34/164 reads (21%) | SIFT tolerated (0.76); PolyPhen benign (0.014); catalogued as rs201337202, COSV57282477; called by muse, mutect2, varscan2
- KCNS2 | c.1031C>A p.S344Y | Missense Mutation (SNP) | VAF 53/210 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54637308, COSV54641660; called by muse, mutect2, varscan2
- KCNT1 | c.2653A>G p.N885D (on ENST00000488444; = p.N904D on NM_020822.3) | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.771); catalogued as COSV53695677; called by muse, mutect2, varscan2
- KDM6A | c.542C>T p.T181I | Missense Mutation (SNP) | VAF 47/237 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.272); catalogued as rs1204365436, COSV65037306; called by muse, mutect2, varscan2
- KIAA0100 | c.6511G>A p.A2171T | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as COSV56380769; called by muse, mutect2, varscan2
- KIAA1841 | c.432G>A p.G144= | Splice Region (SNP) | VAF 41/110 reads (37%) | catalogued as COSV54372701; called by muse, mutect2, varscan2
- KIF17 | c.1324C>T p.R442C | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs562792585, COSV56115839; called by muse, mutect2, varscan2
- KIF18A | c.689C>A p.A230D | Missense Mutation (SNP) | VAF 68/211 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54181149; called by muse, mutect2, varscan2
- KIF1C | c.686G>T p.C229F | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.295); catalogued as COSV57902935; called by muse, mutect2, varscan2
- KIF23 | c.2242C>T p.R748C | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.232); catalogued as rs747635090, COSV52977486; called by muse, mutect2, varscan2
- KIF27 | c.3430C>T p.R1144W | Missense Mutation (SNP) | VAF 102/231 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as rs370478477; called by muse, mutect2, varscan2
- KIF27 | c.2816G>A p.R939H | Missense Mutation (SNP) | VAF 86/232 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs566128018, COSV52825248; called by muse, mutect2, varscan2
- KIF2C | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 71/127 reads (56%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.774); catalogued as rs200680875, COSV64763904; called by muse, mutect2, varscan2
- KLHDC7A | c.2081G>A p.R694H | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1319456377, COSV68769034; called by muse, mutect2, varscan2
- KLHL1 | c.104del p.G35Efs*31 | Frame Shift Del (DEL) | VAF 8/29 reads (28%) | catalogued as rs749011008; called by mutect2, varscan2
- KLHL17 | c.1816G>A p.A606T | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.468); catalogued as rs998598983, COSV58530886; called by muse, mutect2, varscan2
- KLHL25 | c.44C>T p.T15M | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.494); catalogued as rs149329403; called by muse, mutect2, varscan2
- KLHL26 | c.1444G>A p.D482N | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.572); catalogued as COSV56316269; called by muse, mutect2, varscan2
- KLRC1 | c.455C>A p.S152Y | Missense Mutation (SNP) | VAF 152/487 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1327676250, COSV61724787; called by muse, mutect2, varscan2
- KMT2A | c.4087G>A p.E1363K | Missense Mutation (SNP) | VAF 55/171 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV63282180; called by muse, mutect2, varscan2
- KMT2B | c.6026C>T p.A2009V | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT tolerated (0.14); PolyPhen benign (0.306); catalogued as COSV55857231; called by muse, mutect2
- KMT5B | c.1822G>T p.G608C | Missense Mutation (SNP) | VAF 13/142 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.009); catalogued as COSV58563815; called by muse, mutect2
- KRR1 | c.1142del p.K381Sfs*8 | Frame Shift Del (DEL) | VAF 59/141 reads (42%) | catalogued as rs761148574; called by mutect2, varscan2
- KRT12 | c.896A>T p.N299I | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV52429809; called by muse, mutect2, varscan2
- KRT27 | c.535A>G p.N179D | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as COSV56970813; called by muse, mutect2, varscan2
- KRTAP19-1 | c.226T>C p.C76R | Missense Mutation (SNP) | VAF 10/250 reads (4%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.001); catalogued as COSV66860968; called by muse, mutect2
- KRTAP4-12 | c.518G>A p.R173Q | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as rs756965364, COSV101224314; called by muse, mutect2, varscan2
- KYAT3 | c.770A>T p.N257I | Missense Mutation (SNP) | VAF 82/205 reads (40%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.625); catalogued as COSV53098601; called by muse, mutect2, varscan2
- LAMA2 | c.6413G>A p.R2138Q | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1307528497, COSV70339045; called by muse, mutect2, varscan2
- LAMB3 | c.1330T>C p.C444R | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199952752; called by muse, mutect2
- LAMP1 | c.1033C>T p.R345C | Missense Mutation (SNP) | VAF 68/161 reads (42%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.759); catalogued as rs767683537, COSV58148576; called by muse, mutect2, varscan2
- LARP1 | c.906dup p.T303Hfs*19 (on ENST00000518297 / NM_033551.3; = p.T226Hfs*19 on NM_015315.5 and 6 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 52/186 reads (28%) | catalogued as rs769338468; called by mutect2, varscan2
- LCE1C | c.305del p.G102Afs*45 | Frame Shift Del (DEL) | VAF 25/58 reads (43%) | catalogued as rs765643412; called by mutect2, varscan2
- LCOR | c.3457A>T p.K1153* | Nonsense Mutation (SNP) | VAF 51/122 reads (42%) | catalogued as COSV53714467; called by muse, mutect2, varscan2
- LCP1 | c.1103C>T p.A368V | Missense Mutation (SNP) | VAF 9/202 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59939489; called by muse, mutect2
- LEFTY2 | c.683C>T p.A228V | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.037); catalogued as COSV100832682; called by muse, mutect2, varscan2
- LHCGR | c.590C>T p.T197M | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767900216, COSV54292756; called by muse, mutect2, varscan2
- LHX1 | c.1194del p.E399Kfs*2 | Frame Shift Del (DEL) | VAF 10/20 reads (50%) | catalogued as rs775423572; called by mutect2, varscan2
- LIG1 | c.476C>A p.T159N | Missense Mutation (SNP) | VAF 83/235 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.04); catalogued as COSV54389613; called by muse, mutect2
- LIG4 | c.506dup p.S170Efs*13 | Frame Shift Ins (INS) | VAF 78/298 reads (26%) | catalogued as rs1252901419; called by mutect2, pindel, varscan2
- LMBR1 | c.678G>T p.K226N | Missense Mutation (SNP) | VAF 73/118 reads (62%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV62218314; called by muse, mutect2, varscan2
- LMLN | c.523G>A p.V175I | Missense Mutation (SNP) | VAF 44/250 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.072); catalogued as rs770886210, COSV57597946; called by muse, mutect2, varscan2
- LMLN | c.1643G>A p.S548N | Missense Mutation (SNP) | VAF 82/260 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV57597962; called by muse, mutect2, varscan2
- LPIN1 | c.1979G>A p.R660H | Missense Mutation (SNP) | VAF 57/148 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.282); catalogued as rs745398954, COSV56762593; called by muse, mutect2, varscan2
- LPL | c.1059G>C p.E353D | Missense Mutation (SNP) | VAF 35/192 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as rs747267560, COSV60930049; called by muse, mutect2, varscan2
- LRCH3 | c.770C>A p.P257H | Missense Mutation (SNP) | VAF 6/99 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as COSV58389103; called by muse, mutect2
- LRFN3 | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 53/155 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.065); catalogued as COSV55816975; called by muse, mutect2, varscan2
- LRFN4 | c.559G>A p.G187S | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58920693; called by muse, mutect2, varscan2
- LRGUK | c.2423G>A p.R808H | Missense Mutation (SNP) | VAF 92/164 reads (56%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs138421011, COSV53634221; called by muse, mutect2, varscan2
- LRIT2 | c.460A>T p.T154S | Missense Mutation (SNP) | VAF 13/160 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV64518072; called by muse, mutect2
- LRP1 | c.12575del p.P4192Qfs*150 | Frame Shift Del (DEL) | VAF 30/70 reads (43%) | catalogued as rs757410385; called by mutect2, varscan2
- LRP1B | c.13679C>T p.P4560L | Missense Mutation (SNP) | VAF 63/136 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs151022058; called by muse, mutect2, varscan2
- LRP2 | c.4001G>A p.G1334D | Missense Mutation (SNP) | VAF 8/180 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as COSV55541481; called by muse, mutect2
- LRP2BP | c.343G>T p.D115Y | Missense Mutation (SNP) | VAF 71/181 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.249); catalogued as COSV60749275; called by muse, mutect2, varscan2
- LRP3 | c.157C>T p.R53W | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs753467105, COSV53508996; called by muse, mutect2, varscan2
- LRRC14B | c.58del p.Q20Rfs*30 | Frame Shift Del (DEL) | VAF 9/27 reads (33%) | catalogued as COSV52049634; called by mutect2, pindel, varscan2
- LRRC17 | c.1272del p.K424Nfs*12 | Frame Shift Del (DEL) | VAF 40/182 reads (22%) | catalogued as rs745668314; called by mutect2, varscan2
- LRRC47 | c.775C>T p.R259C | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs201066188; called by muse, mutect2, varscan2
- LRRC4B | c.1015C>T p.R339C | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1298920327, COSV65349245; called by muse, mutect2, varscan2
- LTBP1 | c.2467C>T p.P823S (on ENST00000404816 / NM_206943.4; = p.P497S on NM_000627.4) | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.851); catalogued as COSV63180196; called by muse, varscan2
- LTBP3 | c.1965del p.R656Afs*6 | Frame Shift Del (DEL) | VAF 4/10 reads (40%) | catalogued as COSV57240720; called by mutect2, varscan2
- LTBR | c.734_736del p.S245del | In Frame Del (DEL) | VAF 24/82 reads (29%) | catalogued as rs1565495343; called by mutect2, pindel, varscan2
- LYST | c.9257C>A p.A3086D | Missense Mutation (SNP) | VAF 32/218 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV67703470; called by muse, mutect2, varscan2
- MAGEC1 | c.2416G>T p.A806S | Missense Mutation (SNP) | VAF 218/267 reads (82%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.235); catalogued as COSV53568169, COSV53569400; called by muse, mutect2, varscan2
- MAGEE2 | c.133del p.Q45Sfs*27 | Frame Shift Del (DEL) | VAF 19/38 reads (50%) | catalogued as rs1159257962; called by mutect2, pindel, varscan2
- MAN1C1 | c.1296dup p.L433Afs*67 | Frame Shift Ins (INS) | VAF 13/59 reads (22%) | catalogued as rs759630213; called by mutect2, pindel, varscan2
- MAN2B1 | c.1022C>T p.A341V | Missense Mutation (SNP) | VAF 27/169 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.169); catalogued as rs574049175, COSV55470075; called by muse, mutect2, varscan2
- MAP1A | c.6134del p.P2045Qfs*25 | Frame Shift Del (DEL) | VAF 30/102 reads (29%) | catalogued as COSV55810773; called by mutect2, pindel, varscan2
- MAP2 | c.2406G>T p.M802I | Missense Mutation (SNP) | VAF 84/229 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as COSV52281850; called by muse, mutect2, varscan2
- MAP3K6 | c.3608G>A p.R1203Q | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.018); catalogued as rs778526342, COSV58870254; called by muse, mutect2, varscan2
- MARF1 | c.1600C>T p.R534C | Missense Mutation (SNP) | VAF 76/161 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs774267465, COSV60020011; called by muse, mutect2, varscan2
- MBOAT1 | c.582T>G p.S194R | Missense Mutation (SNP) | VAF 32/202 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV61123590; called by muse, mutect2, varscan2
- MBTPS1 | c.2525T>C p.V842A | Missense Mutation (SNP) | VAF 63/144 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV58569408; called by muse, mutect2, varscan2
- MDN1 | c.16495C>T p.R5499* | Nonsense Mutation (SNP) | VAF 59/125 reads (47%) | catalogued as rs1242203123, COSV65517374; called by muse, mutect2, varscan2
- MDN1 | c.5966del p.K1989Rfs*65 | Frame Shift Del (DEL) | VAF 124/318 reads (39%) | catalogued as rs750092100; called by mutect2, varscan2
- MED12 | c.703T>C p.Y235H | Missense Mutation (SNP) | VAF 60/84 reads (71%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); catalogued as COSV61332170; called by muse, mutect2, varscan2
- MED25 | c.602del p.P201Rfs*13 | Frame Shift Del (DEL) | VAF 8/20 reads (40%) | catalogued as rs748546983; ClinVar: uncertain significance; called by mutect2, pindel
- METTL22 | c.389C>T p.A130V | Missense Mutation (SNP) | VAF 93/228 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV50837383; called by muse, mutect2, varscan2
- MGA | c.5978T>G p.V1993G (on ENST00000219905 / NM_001164273.1; = p.V1784G on NM_001080541.2) | Missense Mutation (SNP) | VAF 52/133 reads (39%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.015); catalogued as COSV54949121; called by muse, mutect2, varscan2
- MIB2 | c.730G>A p.A244T | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.4); PolyPhen benign (0.261); catalogued as rs758489915, COSV61755007; called by muse, mutect2
- MICALL2 | c.2054del p.P685Lfs*40 | Frame Shift Del (DEL) | VAF 22/97 reads (23%) | catalogued as rs1292764952; called by mutect2, pindel, varscan2
- MINAR1 | c.2104del p.S702Afs*11 | Frame Shift Del (DEL) | VAF 28/165 reads (17%) | catalogued as rs748072217, COSV59581461; called by mutect2, varscan2
- MKI67 | c.2349G>C p.L783F | Missense Mutation (SNP) | VAF 13/254 reads (5%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.96); catalogued as COSV64072635; called by muse, mutect2
- MLIP | c.478C>T p.R160W | Missense Mutation (SNP) | VAF 70/212 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs769959762, COSV51426013; called by muse, mutect2
- MMEL1 | c.2323C>T p.R775* | Nonsense Mutation (SNP) | VAF 5/14 reads (36%) | catalogued as rs751727727, COSV56518592; called by muse, mutect2, varscan2
- MMP27 | c.1464G>T p.K488N | Missense Mutation (SNP) | VAF 81/192 reads (42%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); catalogued as rs751907461, COSV52779831, COSV52782270, COSV52782352; called by muse, mutect2, varscan2
- MMS22L | c.851T>C p.M284T | Missense Mutation (SNP) | VAF 26/276 reads (9%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs1170163637, COSV51516819; called by muse, mutect2
- MPIG6B | c.88C>T p.R30W | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as rs867304850, COSV65389292; called by muse, mutect2, varscan2
- MPP4 | c.345G>T p.Q115H | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.663); catalogued as COSV59628821; called by muse, mutect2, varscan2
- MPRIP | c.1774C>T p.R592C | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs770423449, COSV57925568; called by muse, mutect2
- MROH2B | c.4114del p.I1372Sfs*5 | Frame Shift Del (DEL) | VAF 59/199 reads (30%) | catalogued as rs756600463; called by mutect2, varscan2
- MROH6 | c.1823G>A p.R608Q | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.023); catalogued as rs764173855, COSV52796427, COSV99369657; called by muse, mutect2, varscan2
- MROH8 | c.1482dup p.N495Kfs*4 | Frame Shift Ins (INS) | VAF 23/132 reads (17%) | catalogued as rs1483444302; called by mutect2, pindel, varscan2
- MRPL24 | c.470C>A p.P157H | Missense Mutation (SNP) | VAF 17/154 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61975608; called by muse, mutect2, varscan2
- MS4A8 | c.53C>A p.A18E | Missense Mutation (SNP) | VAF 117/291 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.421); catalogued as COSV55753141; called by muse, mutect2, varscan2
- MSN | c.1555C>A p.Q519K | Missense Mutation (SNP) | VAF 15/19 reads (79%) | SIFT tolerated (0.24); PolyPhen benign (0.03); catalogued as COSV64303245; called by muse, mutect2, varscan2
- MTMR6 | c.738G>A p.M246I | Missense Mutation (SNP) | VAF 45/109 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.019); catalogued as COSV67807809; called by muse, mutect2, varscan2
- MTRR | c.1535G>A p.R512Q (on ENST00000264668; = p.R485Q on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 73/215 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs146475928; called by muse, mutect2, varscan2
- MUC16 | c.15983del p.P5328Lfs*11 | Frame Shift Del (DEL) | VAF 11/90 reads (12%) | catalogued as rs752658892; called by mutect2, pindel, varscan2
- MYH2 | c.5002C>T p.R1668W | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs569489518, COSV55431886, COSV55435762; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH7 | c.1372G>A p.G458R | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62516353; called by muse, mutect2, varscan2
- MYL4 | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs767035280, COSV100733195; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO10 | c.2005C>T p.R669C | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs966456527, COSV57016963, COSV57031889; called by muse, mutect2, varscan2
- MYO1A | c.1675C>T p.R559C | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs372055709; called by muse, mutect2, varscan2
- MYO9B | c.2647C>T p.R883C | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.515); catalogued as rs775138361, COSV68277071; called by muse, varscan2
- MYOM2 | c.2999A>G p.E1000G | Missense Mutation (SNP) | VAF 48/264 reads (18%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.697); catalogued as COSV50702436; called by muse, mutect2, varscan2
- MYT1 | c.3209G>C p.S1070T | Missense Mutation (SNP) | VAF 55/256 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV60501244; called by muse, mutect2, varscan2
- NAALAD2 | c.980A>G p.D327G | Missense Mutation (SNP) | VAF 48/156 reads (31%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV58958764, COSV58964483; called by muse, mutect2, varscan2
- NAPEPLD | c.842del p.F281Sfs*14 | Frame Shift Del (DEL) | VAF 53/186 reads (28%) | catalogued as rs746683932, COSV100439928; called by mutect2, varscan2
- NAV2 | c.3283G>A p.A1095T (on ENST00000396087 / NM_001244963.2; = p.A1072T on NM_145117.5) | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.652); catalogued as rs751815417, COSV60656569; called by muse, mutect2, varscan2
- NAV3 | c.4858G>T p.A1620S | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.219); catalogued as COSV57062774; called by muse, mutect2, varscan2
- NBEAL2 | c.1943C>T p.A648V | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs372051707; called by muse, mutect2, varscan2
- NCAM2 | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 60/127 reads (47%) | SIFT tolerated (0.54); PolyPhen benign (0.093); catalogued as rs898441273, COSV53057228, COSV99525718; called by muse, mutect2, varscan2
- NCAPD3 | c.652C>T p.H218Y | Missense Mutation (SNP) | VAF 38/148 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.037); catalogued as COSV73257880; called by muse, mutect2, varscan2
- NCAPH | c.248G>A p.R83H | Missense Mutation (SNP) | VAF 73/177 reads (41%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs759878969, COSV53634935; called by muse, mutect2, varscan2
- NCBP1 | c.343T>A p.S115T | Missense Mutation (SNP) | VAF 110/278 reads (40%) | SIFT tolerated (0.57); PolyPhen benign (0.014); catalogued as COSV64316469; called by muse, mutect2, varscan2
- NCOA2 | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 25/448 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.219); catalogued as COSV71763476; called by muse, mutect2
- NCOR2 | c.944G>A p.R315H | Missense Mutation (SNP) | VAF 75/179 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1012459312, COSV62293396; called by muse, mutect2, varscan2
- NEBL | c.1678T>C p.Y560H | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65801459; called by muse, mutect2, varscan2
- NID1 | c.3160C>T p.Q1054* | Nonsense Mutation (SNP) | VAF 74/156 reads (47%) | catalogued as COSV51615178; called by muse, mutect2, varscan2
- NIN | c.2830C>T p.H944Y | Missense Mutation (SNP) | VAF 11/324 reads (3%) | SIFT tolerated (0.48); PolyPhen benign (0.439); catalogued as COSV55380671; called by muse, mutect2
- NINL | c.3208C>T p.R1070W | Missense Mutation (SNP) | VAF 80/356 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs763755978, COSV53998719, COSV54009676; called by muse, mutect2, varscan2
- NKIRAS2 | c.157del p.V53Cfs*78 | Frame Shift Del (DEL) | VAF 28/72 reads (39%) | catalogued as COSV100288809; called by mutect2, pindel, varscan2
- NLRP10 | c.452C>T p.T151M | Missense Mutation (SNP) | VAF 43/132 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs775641848, COSV60778738; called by muse, mutect2, varscan2
- NLRP13 | c.1254_1255del p.F419Sfs*55 | Frame Shift Del (DEL) | VAF 52/188 reads (28%) | catalogued as rs769359952; called by pindel, varscan2
- NLRP3 | c.1324G>A p.V442I | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs201252712, COSV60220253; called by muse, mutect2, varscan2
- NOA1 | c.1489A>G p.T497A | Missense Mutation (SNP) | VAF 25/492 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51736000; called by muse, mutect2
- NOP53 | c.613C>T p.P205S | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.172); catalogued as COSV55881122; called by muse, mutect2, varscan2
- NOTCH1 | c.7540C>A p.P2514T | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV53029448, COSV53030823; called by muse, mutect2, varscan2
- NPAT | c.2786-3del | Splice Region (DEL) | VAF 35/117 reads (30%) | catalogued as rs35747263; called by mutect2, pindel, varscan2
- NPBWR1 | c.47G>A p.G16D | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV58695427; called by muse, mutect2, varscan2
- NPHP4 | c.593C>T p.A198V | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs370410995; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NPTXR | c.1243A>G p.K415E | Missense Mutation (SNP) | VAF 47/132 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.223); catalogued as COSV60727692; called by muse, mutect2, varscan2
- NRDE2 | c.268del p.R90Gfs*69 | Frame Shift Del (DEL) | VAF 40/248 reads (16%) | catalogued as rs1249617548, COSV62963847; called by mutect2, pindel, varscan2
- NRP2 | c.1322T>C p.L441P | Missense Mutation (SNP) | VAF 66/409 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV55923520; called by muse, mutect2, varscan2
- NSD2 | c.1799G>A p.R600Q | Missense Mutation (SNP) | VAF 52/117 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1189008609, COSV56386668; called by muse, mutect2, varscan2
- NTAN1 | c.890dup p.N297Kfs*2 | Frame Shift Ins (INS) | VAF 76/236 reads (32%) | catalogued as rs753931847; called by mutect2, varscan2
- NTNG2 | c.670G>A p.G224S | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62364465; called by muse, varscan2
- NUAK1 | c.1720G>A p.D574N | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.234); catalogued as rs186215853; called by muse, mutect2, varscan2
- NUP214 | c.3797A>G p.E1266G | Missense Mutation (SNP) | VAF 66/146 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as COSV63907692; called by muse, mutect2, varscan2
- OGA | c.1618C>T p.P540S | Missense Mutation (SNP) | VAF 30/376 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.062); catalogued as rs1300858963, COSV63380939; called by muse, mutect2
- OPTN | c.76del p.H26Tfs*19 | Frame Shift Del (DEL) | VAF 56/178 reads (31%) | catalogued as rs753966040; called by mutect2, pindel, varscan2
- OR10C1 | c.698C>T p.A233V (on ENST00000622521; = p.A231V on NM_013941.3) | Missense Mutation (SNP) | VAF 136/394 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV65822262; called by muse, mutect2, varscan2
- OR10H5 | c.196C>A p.L66I | Missense Mutation (SNP) | VAF 47/151 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58277465; called by muse, mutect2, varscan2
- OR2A5 | c.854T>G p.L285R | Missense Mutation (SNP) | VAF 95/207 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs775737662, COSV68738521; called by muse, mutect2, varscan2
- OR2T3 | c.655A>G p.I219V | Missense Mutation (SNP) | VAF 142/189 reads (75%) | SIFT tolerated (0.15); PolyPhen benign (0.308); catalogued as COSV62081774; called by muse, mutect2, varscan2
- OR4C46 | c.16A>G p.N6D | Missense Mutation (SNP) | VAF 35/197 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.216); catalogued as rs757308478, COSV60218285, COSV60218402; called by muse, mutect2, varscan2
- OR51V1 | c.308A>G p.Q103R | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58314142; called by muse, mutect2
- OR52A5 | c.194del p.L65Wfs*20 | Frame Shift Del (DEL) | VAF 36/122 reads (30%) | catalogued as rs762677866, COSV100263457; called by mutect2, pindel, varscan2
- OR5D18 | c.536_538del p.F179del | In Frame Del (DEL) | VAF 126/383 reads (33%) | catalogued as rs765138366; called by pindel, varscan2
- OR5J2 | c.608C>A p.S203Y | Missense Mutation (SNP) | VAF 89/198 reads (45%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.983); catalogued as COSV56620231, COSV56621042; called by muse, mutect2, varscan2
- OR5K2 | c.237del p.M81Cfs*2 | Frame Shift Del (DEL) | VAF 152/382 reads (40%) | catalogued as COSV101415985; called by mutect2, varscan2
- OR8G1 | c.368A>G p.Y123C | Missense Mutation (SNP) | VAF 49/274 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.623); catalogued as COSV100422710; called by muse, mutect2, varscan2
- ORAI1 | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.76); PolyPhen benign (0.007); catalogued as rs529121117, COSV57490932; called by muse, mutect2, varscan2
- P2RY4 | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs1181460010, COSV65736278; called by muse, mutect2
- PACS2 | c.287_289del p.F96del | In Frame Del (DEL) | VAF 54/172 reads (31%) | catalogued as rs1425778118; called by mutect2, pindel, varscan2
- PACS2 | c.1760T>A p.I587N | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57650057; called by muse, mutect2
- PADI3 | c.1374del p.V459Wfs*17 | Frame Shift Del (DEL) | VAF 16/119 reads (13%) | catalogued as rs747531633; called by mutect2, pindel, varscan2
- PAMR1 | c.302del p.G101Vfs*8 | Frame Shift Del (DEL) | VAF 99/352 reads (28%) | catalogued as rs751755759; called by mutect2, varscan2
- PAN3 | c.1318G>A p.A440T | Missense Mutation (SNP) | VAF 109/285 reads (38%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.748); catalogued as rs765586023, COSV56701201; called by muse, mutect2, varscan2
- PAPLN | c.2000C>A p.P667H (on ENST00000554301; = p.P640H on NM_173462.4) | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV53713232; called by muse, mutect2, varscan2
- PAPPA2 | c.5055del p.S1686Vfs*4 | Frame Shift Del (DEL) | VAF 49/132 reads (37%) | catalogued as rs747970462, COSV62809272; called by mutect2, pindel, varscan2
- PAXIP1 | c.2020G>A p.A674T | Missense Mutation (SNP) | VAF 60/105 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68184797; called by muse, mutect2, varscan2
- PBXIP1 | c.73G>T p.G25C | Missense Mutation (SNP) | VAF 74/171 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV63776760; called by muse, mutect2, varscan2
- PCCA | c.689G>A p.R230H | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs747943045, COSV66187867; called by muse, mutect2, varscan2
- PCDH17 | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs202073176, COSV64971802; called by muse, mutect2, varscan2
- PCDH18 | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 136/401 reads (34%) | SIFT tolerated (0.77); PolyPhen benign (0.017); catalogued as COSV61266479; called by muse, mutect2, varscan2
- PCDHA13 | c.763G>A p.A255T | Missense Mutation (SNP) | VAF 66/216 reads (31%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.097); catalogued as COSV56478965; called by muse, mutect2, varscan2
- PCDHA3 | c.2050G>A p.A684T | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); catalogued as rs782577100, COSV63538996; called by muse, mutect2, varscan2
- PCDHA4 | c.2276G>A p.C759Y | Missense Mutation (SNP) | VAF 30/153 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.038); catalogued as COSV63539001; called by muse, mutect2, varscan2
- PCDHB12 | c.449C>T p.A150V | Missense Mutation (SNP) | VAF 72/199 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); catalogued as rs1563976628, COSV53392950; called by muse, mutect2, varscan2
- PCDHGB7 | c.1888C>T p.R630C | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1322393151, COSV53901619; called by muse, mutect2, varscan2
- PCK2 | c.1234+3A>G | Splice Region (SNP) | VAF 21/64 reads (33%) | catalogued as COSV99394717; called by muse, varscan2
- PCNT | c.3595G>A p.A1199T | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT tolerated (0.14); PolyPhen benign (0.253); catalogued as rs1227674808, COSV64025186; called by muse, mutect2, varscan2
- PDCD11 | c.1037G>A p.R346H | Missense Mutation (SNP) | VAF 51/118 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.062); catalogued as rs548314013, COSV63933072; called by muse, mutect2, varscan2
- PDCD6IP | c.602del p.L201* | Frame Shift Del (DEL) | VAF 86/212 reads (41%) | catalogued as rs781474699; called by mutect2, varscan2
- PDCD6IP | c.2489A>T p.N830I | Missense Mutation (SNP) | VAF 69/184 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as COSV56241231; called by muse, mutect2, varscan2
- PDGFC | c.947G>A p.G316D | Missense Mutation (SNP) | VAF 74/162 reads (46%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV56845284; called by muse, mutect2, varscan2
- PDGFRA | c.1834G>A p.A612T | Missense Mutation (SNP) | VAF 59/160 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs1290211365, COSV57264909; called by muse, mutect2, varscan2
- PDGFRB | c.2084G>A p.R695H | Missense Mutation (SNP) | VAF 19/136 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs375978065; called by muse, mutect2, varscan2
- PDZRN4 | c.2893C>T p.R965* (on ENST00000402685 / NM_001164595.2; = p.R707* on NM_013377.4) | Nonsense Mutation (SNP) | VAF 18/59 reads (31%) | catalogued as rs761186901, COSV54192369; called by muse, mutect2, varscan2
- PEAK1 | c.2909G>A p.R970H | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs745782057, COSV56930899; called by muse, mutect2, varscan2
- PELI2 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.44); PolyPhen benign (0.2); catalogued as rs772176782, COSV50710005; called by muse, mutect2, varscan2
- PEX14 | c.170-1G>T p.X57_splice | Splice Site (SNP) | VAF 37/126 reads (29%) | catalogued as COSV63059869; called by muse, mutect2, varscan2
- PFKL | c.1996G>A p.A666T | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0.063); catalogued as rs752429204, COSV57394143; called by muse, mutect2, varscan2
- PGBD4 | c.1751del p.N584Ifs*21 | Frame Shift Del (DEL) | VAF 32/130 reads (25%) | catalogued as rs770560794; called by mutect2, varscan2
- PGR | c.994G>A p.G332R | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as rs757746136, COSV54796515; called by muse, mutect2, varscan2
- PHF2 | c.1475del p.K492Rfs*6 | Frame Shift Del (DEL) | VAF 10/21 reads (48%) | catalogued as rs769717544; called by mutect2, varscan2
- PHLPP2 | c.2858T>G p.L953R | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62422625; called by muse, mutect2, varscan2
- PI4KA | c.3490G>T p.G1164C | Missense Mutation (SNP) | VAF 63/189 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.502); catalogued as COSV55404314; called by muse, mutect2, varscan2
- PIGL | c.592C>T p.P198S | Missense Mutation (SNP) | VAF 48/183 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV56683776; called by muse, mutect2, varscan2
- PIGT | c.1043del p.P348Qfs*11 | Frame Shift Del (DEL) | VAF 16/74 reads (22%) | catalogued as rs749895437; called by mutect2, pindel
- PIK3C2A | c.340del p.T114Hfs*10 | Frame Shift Del (DEL) | VAF 132/350 reads (38%) | catalogued as COSV56402935; called by mutect2, pindel, varscan2
- PIK3R4 | c.2255G>A p.R752Q | Missense Mutation (SNP) | VAF 62/147 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774080288, COSV63239187; called by muse, mutect2, varscan2
- PIP5K1A | c.1685A>G p.H562R (on ENST00000368888 / NM_001135638.2; = p.H549R on NM_003557.3) | Missense Mutation (SNP) | VAF 24/185 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as rs760279547, COSV62957402; called by muse, mutect2, varscan2
- PITPNA | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.994); catalogued as COSV57932285; called by muse, mutect2, varscan2
- PKD1 | c.12376G>A p.D4126N (on ENST00000262304 / NM_001009944.3; = p.D4125N on NM_000296.4) | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1359957327, COSV51910846; called by muse, mutect2, varscan2
- PKHD1L1 | c.10801G>A p.A3601T | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV65737432; called by muse, mutect2, varscan2
- PKN3 | c.2496G>T p.Q832H | Missense Mutation (SNP) | VAF 82/212 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as COSV52574913; called by muse, mutect2, varscan2
- PKP4 | c.1009T>C p.S337P | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.949); catalogued as COSV67675719; called by muse, mutect2, varscan2
- PLAG1 | c.251C>A p.A84D | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57609346; called by muse, mutect2, varscan2
- PLCB1 | c.3111+1G>A p.X1037_splice | Splice Site (SNP) | VAF 11/142 reads (8%) | catalogued as COSV62038986; called by muse, mutect2
- PLCG2 | c.1882G>A p.E628K | Missense Mutation (SNP) | VAF 101/281 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV63867552, COSV63879236; called by muse, mutect2, varscan2
- PLCXD1 | c.556C>T p.P186S | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as COSV67541501; called by muse, mutect2
- PLD2 | c.2374G>A p.E792K | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as rs369879187, COSV99562523; called by muse, mutect2, varscan2
- PLEC | c.12287G>A p.R4096H (on ENST00000322810 / NM_201380.4; = p.R3986H on NM_000445.5) | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs782457644, COSV100519779; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLEKHA2 | c.61A>G p.N21D | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV66242093; called by muse, mutect2, varscan2
- PLEKHA7 | c.2405del p.F802Sfs*21 | Frame Shift Del (DEL) | VAF 108/266 reads (41%) | catalogued as rs1333390805, COSV63043367; called by mutect2, varscan2
- PLEKHG4B | c.2809del p.V937Cfs*59 (on ENST00000283426; = p.V1293Cfs*59 on NM_052909.5) | Frame Shift Del (DEL) | VAF 11/30 reads (37%) | catalogued as COSV52043730; called by mutect2, varscan2
- PLEKHM1 | c.1082C>T p.A361V | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as rs777658964, COSV69598522; called by muse, mutect2, varscan2
- PLEKHM3 | c.1513C>T p.R505* | Nonsense Mutation (SNP) | VAF 5/100 reads (5%) | catalogued as rs1416993669, COSV66815589; called by muse, mutect2
- PLIN5 | c.1066G>A p.A356T | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs575416554, COSV67850369; called by muse, mutect2
- PLPP7 | c.718G>A p.V240I | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.097); catalogued as rs146890476; called by muse, mutect2, varscan2
- PLXDC2 | c.808A>T p.S270C | Missense Mutation (SNP) | VAF 9/134 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as COSV65900919; called by muse, mutect2
- PLXNA1 | c.4184C>T p.T1395M | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as rs775284582, COSV52522400; called by muse, mutect2, varscan2
- PNPLA6 | c.3161C>T p.T1054M (on ENST00000414982 / NM_001166111.2; = p.T1006M on NM_006702.5) | Missense Mutation (SNP) | VAF 84/249 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1379163374, COSV55373925; called by muse, mutect2, varscan2
- PODN | c.1771G>A p.D591N (on ENST00000395871; = p.D543N on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT tolerated (0.54); PolyPhen benign (0.248); catalogued as rs534137326, COSV57010565; called by muse, mutect2, varscan2
- POFUT2 | c.526A>G p.R176G | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57957882; called by muse, mutect2
- POLD3 | c.898del p.R300Gfs*5 | Frame Shift Del (DEL) | VAF 14/40 reads (35%) | catalogued as rs761423306, COSV55240660; called by mutect2, varscan2
- POLE | c.5900C>T p.A1967V | Missense Mutation (SNP) | VAF 63/135 reads (47%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs201273415; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- POLR3A | c.3019A>G p.T1007A | Missense Mutation (SNP) | VAF 65/138 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as COSV64930263; called by muse, mutect2, varscan2
- POMT1 | c.629C>T p.T210M | Missense Mutation (SNP) | VAF 124/340 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs377037072; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POTEE | c.2057del p.K686Rfs*6 | Frame Shift Del (DEL) | VAF 8/49 reads (16%) | catalogued as rs772047281; called by mutect2, varscan2
- POU4F3 | c.832C>T p.R278C | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57942451; called by muse, mutect2, varscan2
- PPEF2 | c.1048G>A p.E350K | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs1488439021, COSV54420248, COSV54420279; called by muse, mutect2, varscan2
- PPFIA2 | c.541_544del p.F181Sfs*10 | Frame Shift Del (DEL) | VAF 52/144 reads (36%) | catalogued as rs1400362499; called by pindel, varscan2
- PPFIBP1 | c.1197G>T p.E399D (on ENST00000318304 / NM_177444.3; = p.E382D on NM_003622.4) | Missense Mutation (SNP) | VAF 18/163 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.155); catalogued as COSV57287796; called by muse, mutect2, varscan2
- PPHLN1 | c.995T>A p.F332Y | Missense Mutation (SNP) | VAF 82/205 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV56728547; called by muse, mutect2, varscan2
- PPL | c.1501G>A p.D501N | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.276); catalogued as COSV62044661; called by muse, mutect2, varscan2
- PPP1R10 | c.1295C>T p.A432V | Missense Mutation (SNP) | VAF 74/181 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV64738500; called by muse, mutect2, varscan2
- PPP1R13B | c.2947T>G p.S983A | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.987); catalogued as COSV52448814; called by muse, mutect2, varscan2
- PPP1R8 | c.758G>A p.R253H (on ENST00000311772 / NM_014110.5; = p.R29H on NM_002713.4) | Missense Mutation (SNP) | VAF 211/546 reads (39%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs200306314, COSV52579378; called by muse, mutect2, varscan2
- PRAG1 | c.1072G>A p.V358I | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs186437273, COSV58157495; called by muse, varscan2
- PRDM10 | c.2789C>T p.S930L | Missense Mutation (SNP) | VAF 22/372 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.452); catalogued as rs561725124, COSV58799398; called by muse, mutect2
- PREX2 | c.1693del p.S565Rfs*10 | Frame Shift Del (DEL) | VAF 54/250 reads (22%) | catalogued as rs764112302; called by mutect2, varscan2
- PRKD2 | c.1546G>A p.A516T | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.043); catalogued as rs774048512, COSV52184657; called by muse, mutect2, varscan2
- PRKG2 | c.89T>C p.V30A | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.095); catalogued as COSV52319361; called by muse, mutect2, varscan2
- PRLHR | c.491T>C p.V164A | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.79); PolyPhen benign (0.005); catalogued as COSV53302870; called by muse, mutect2, varscan2
- PROS1 | c.1079A>T p.E360V | Missense Mutation (SNP) | VAF 62/195 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM163581, COSV67774314; called by muse, mutect2, varscan2
- PROX1 | c.477T>A p.D159E | Missense Mutation (SNP) | VAF 68/162 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV54776096; called by muse, mutect2, varscan2
- PRRC2B | c.2057C>T p.T686M | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.53); catalogued as rs765308056, COSV61933826; called by mutect2, varscan2
- PRRG1 | c.401del p.P134Hfs*19 | Frame Shift Del (DEL) | VAF 94/113 reads (83%) | catalogued as rs781858060; called by mutect2, varscan2
- PRSS36 | c.1052C>T p.A351V | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs200868172, COSV51635783; called by muse, mutect2, varscan2
- PRSS38 | c.692C>A p.A231D | Missense Mutation (SNP) | VAF 5/90 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64539666; called by muse, mutect2
- PRX | c.3845C>T p.S1282L | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.371); catalogued as rs753530396, COSV52519175, COSV52524680; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PSAP | c.131C>T p.A44V | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs750553571, COSV101206543; called by mutect2, varscan2
- PSD | c.2588G>A p.R863H | Missense Mutation (SNP) | VAF 83/193 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs368237669, COSV50041867; called by muse, mutect2, varscan2
- PSD2 | c.1070C>T p.S357L | Missense Mutation (SNP) | VAF 43/102 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.338); catalogued as rs767761922, COSV51197129; called by muse, mutect2, varscan2
- PSMA1 | c.664A>G p.T222A | Missense Mutation (SNP) | VAF 67/173 reads (39%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV67165712; called by muse, mutect2, varscan2
- PSMB3 | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as rs771740744; called by muse, mutect2, varscan2
- PSMC3 | c.454-1G>T p.X152_splice | Splice Site (SNP) | VAF 88/233 reads (38%) | catalogued as COSV54080203; called by muse, mutect2, varscan2
- PSPC1 | c.1530dup p.G511Rfs*5 | Frame Shift Ins (INS) | VAF 29/158 reads (18%) | catalogued as COSV100142410; called by mutect2, pindel, varscan2
- PTAFR | c.619C>A p.L207M | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.17); catalogued as COSV59536083; called by muse, mutect2, varscan2
- PTCH1 | c.2258T>C p.V753A | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.705); catalogued as COSV59463394; called by muse, mutect2
- PTCH2 | c.2303C>T p.A768V | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT tolerated (0.4); PolyPhen benign (0.154); catalogued as rs761442845, COSV64709764; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTCHD3 | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.039); catalogued as COSV71256305, COSV71256830; called by muse, mutect2, varscan2
- PTK2 | c.1153C>T p.R385W | Missense Mutation (SNP) | VAF 184/836 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.895); catalogued as rs1042391332, COSV61782661; called by muse, mutect2, varscan2
- PTPN13 | c.4604del p.K1535Sfs*16 (on ENST00000411767 / NM_080683.3; = p.K1516Sfs*16 on NM_006264.3) | Frame Shift Del (DEL) | VAF 68/186 reads (37%) | catalogued as rs1565531675; called by mutect2, pindel, varscan2
- PTPRS | c.4658C>T p.T1553M | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.37); PolyPhen probably damaging (1); catalogued as rs182037655, COSV53623717; called by muse, mutect2, varscan2
- PTPRU | c.3592G>A p.A1198T | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.175); catalogued as COSV60522231; called by muse, mutect2, varscan2
- PURG | c.341A>G p.E114G | Missense Mutation (SNP) | VAF 54/341 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.157); catalogued as COSV53296248; called by muse, mutect2
- PUS3 | c.338G>A p.R113Q | Missense Mutation (SNP) | VAF 231/673 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1440895074, COSV57102103; called by muse, mutect2, varscan2
- PYHIN1 | c.785A>G p.K262R | Missense Mutation (SNP) | VAF 45/113 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV63721341; called by muse, mutect2, varscan2
- RAB14 | c.105del p.K35Nfs*18 | Frame Shift Del (DEL) | VAF 90/191 reads (47%) | catalogued as rs1564320972; called by mutect2, varscan2
- RALGDS | c.2407C>T p.R803C | Missense Mutation (SNP) | VAF 8/178 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64425629; called by muse, mutect2
- RANBP9 | c.1513G>A p.A505T | Missense Mutation (SNP) | VAF 58/169 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs780793088, COSV50580211; called by muse, mutect2, varscan2
- RASA1 | c.1582T>C p.Y528H | Missense Mutation (SNP) | VAF 94/221 reads (43%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.869); catalogued as COSV57191539; called by muse, mutect2, varscan2
- RAVER2 | c.380C>T p.S127F | Missense Mutation (SNP) | VAF 106/275 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as COSV53805088; called by muse, mutect2, varscan2
- RBM11 | c.183A>C p.E61D | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.47); catalogued as COSV68747939; called by muse, mutect2
- RC3H2 | c.812G>A p.R271Q | Missense Mutation (SNP) | VAF 46/135 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs777562155, COSV59010468; called by muse, mutect2, varscan2
- RCOR3 | c.830T>A p.F277Y | Missense Mutation (SNP) | VAF 43/122 reads (35%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as COSV65364604; called by muse, mutect2, varscan2
- REV1 | c.2662T>C p.C888R | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.467); catalogued as rs1204350618, COSV51481914; called by muse, mutect2, varscan2
- REV1 | c.2023A>C p.T675P | Missense Mutation (SNP) | VAF 9/243 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.368); catalogued as COSV51481927; called by muse, mutect2
- REV1 | c.1696G>A p.A566T | Missense Mutation (SNP) | VAF 46/119 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51481940; called by muse, mutect2, varscan2
- REV3L | c.3580C>T p.R1194* | Nonsense Mutation (SNP) | VAF 85/282 reads (30%) | catalogued as rs1417729268, COSV62615312; called by muse, mutect2, varscan2
- REXO4 | c.910+2T>C p.X304_splice | Splice Site (SNP) | VAF 16/420 reads (4%) | catalogued as COSV64241214; called by muse, mutect2
- RGS12 | c.3410C>T p.T1137M | Missense Mutation (SNP) | VAF 54/140 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.179); catalogued as rs777956928, COSV58748838; called by muse, mutect2, varscan2
- RGS8 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 78/160 reads (49%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.499); catalogued as rs1403042683, COSV51115013; called by muse, mutect2, varscan2
- RIF1 | c.1414del p.S472Pfs*34 | Frame Shift Del (DEL) | VAF 33/213 reads (15%) | catalogued as COSV54616696; called by mutect2, pindel, varscan2
- RIMS2 | c.4152G>T p.Q1384H (on ENST00000666250 / NM_001348490.2; = p.Q955H on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/257 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV51654322; called by muse, mutect2, varscan2
- RLF | c.4255del p.Y1419Ifs*6 | Frame Shift Del (DEL) | VAF 22/162 reads (14%) | catalogued as COSV65652466; called by mutect2, pindel, varscan2
- RMND5A | c.586A>G p.R196G | Missense Mutation (SNP) | VAF 9/250 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52152794; called by muse, mutect2
- RNF213 | c.13537G>A p.V4513M | Missense Mutation (SNP) | VAF 165/402 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs148541222; called by muse, mutect2, varscan2
- RNF213 | c.15178A>G p.T5060A | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.029); catalogued as COSV60390596; called by muse, mutect2
- RNF31 | c.1669G>T p.A557S | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.514); catalogued as rs1339818195, COSV53758474; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 77/151 reads (51%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- ROBO1 | c.2265del p.F755Lfs*28 | Frame Shift Del (DEL) | VAF 19/66 reads (29%) | catalogued as rs1192824348; called by mutect2, pindel, varscan2
- ROR1 | c.1174G>A p.D392N | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs1352060656, COSV64284008; called by muse, mutect2, varscan2
- RP1 | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 80/357 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as COSV55110392; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 28/80 reads (35%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPL6 | c.226G>A p.A76T | Missense Mutation (SNP) | VAF 107/294 reads (36%) | SIFT tolerated (0.62); PolyPhen benign (0.011); catalogued as rs1390429793, COSV52516470; called by muse, mutect2, varscan2
- RPS6KA1 | c.1104dup p.S369Qfs*47 | Frame Shift Ins (INS) | VAF 30/94 reads (32%) | catalogued as rs745561139; called by mutect2, varscan2
- RPS6KL1 | c.1552G>A p.E518K | Missense Mutation (SNP) | VAF 71/150 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.136); catalogued as rs559466508, COSV53165581, COSV99471936; called by muse, mutect2, varscan2
- RSAD1 | c.607C>T p.Q203* | Nonsense Mutation (SNP) | VAF 28/78 reads (36%) | catalogued as COSV51954680; called by muse, mutect2, varscan2
- RSBN1 | c.2056T>C p.F686L | Missense Mutation (SNP) | VAF 124/288 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.104); catalogued as COSV54731102; called by muse, mutect2, varscan2
- RSPH3 | c.1333del p.T445Pfs*15 (on ENST00000252655; = p.T303Pfs*15 on NM_031924.8) | Frame Shift Del (DEL) | VAF 41/109 reads (38%) | catalogued as COSV51922348, COSV51923961; called by mutect2, pindel, varscan2
- RTCB | c.491A>G p.N164S | Missense Mutation (SNP) | VAF 99/211 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV53277330; called by muse, mutect2, varscan2
- RTEL1 | c.2351_2353del p.F784del | In Frame Del (DEL) | VAF 16/64 reads (25%) | catalogued as rs771771098; called by pindel, varscan2
- RTP1 | c.689C>T p.T230M | Missense Mutation (SNP) | VAF 44/115 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1488791051, COSV56617700; called by muse, mutect2, varscan2
- RTTN | c.1503G>A p.M501I | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs983058506, COSV55341522; called by muse, mutect2, varscan2
- RUNX1T1 | c.273del p.S92Hfs*35 (on ENST00000265814 / NM_001198628.1; = p.S65Hfs*35 on NM_004349.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 16/97 reads (16%) | catalogued as rs1258994032; called by mutect2, pindel, varscan2
- RUSC2 | c.3130G>A p.V1044I | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT tolerated (0.39); PolyPhen benign (0.298); catalogued as rs147279845, COSV63427676; called by muse, mutect2, varscan2
- RUVBL2 | c.280C>A p.L94M | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); catalogued as COSV55484257; called by muse, mutect2, varscan2
- RWDD2B | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 9/147 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV54501097; called by muse, mutect2
- RXFP3 | c.575G>A p.R192Q | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.109); catalogued as rs754146433, COSV100347200, COSV57504137; called by muse, mutect2, varscan2
- RYR3 | c.8699C>T p.A2900V (on ENST00000389232; = p.A2901V on NM_001036.6) | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.542); catalogued as rs1400117455, COSV66778488; called by muse, mutect2
- S100A16 | c.115C>T p.R39C | Missense Mutation (SNP) | VAF 50/108 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs142272783, COSV64182940; called by muse, mutect2, varscan2
- SACS | c.7693T>C p.F2565L | Missense Mutation (SNP) | VAF 10/273 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.057); catalogued as COSV66534596; called by muse, mutect2
- SALL1 | c.884C>T p.A295V | Missense Mutation (SNP) | VAF 47/134 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV51753437; called by muse, mutect2, varscan2
- SBF1 | c.5152-2A>C p.X1718_splice | Splice Site (SNP) | VAF 20/55 reads (36%) | catalogued as COSV53290269; called by muse, mutect2, varscan2
- SCAF8 | c.475+2T>C p.X159_splice | Splice Site (SNP) | VAF 21/103 reads (20%) | catalogued as COSV65790037; called by muse, mutect2, varscan2
- SCN4A | c.3286G>A p.A1096T | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs766002690, COSV71125645; called by muse, mutect2, varscan2
- SCO1 | c.131T>A p.F44Y | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.047); catalogued as COSV55134925; called by muse, mutect2, varscan2
- SDK1 | c.4646A>G p.Y1549C | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV67357110; called by muse, mutect2, varscan2
- SEC24C | c.3035G>A p.S1012N | Missense Mutation (SNP) | VAF 196/596 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs752433866, COSV59540026, COSV59544141; called by muse, mutect2, varscan2
- SEC63 | c.1586_1596delinsGAAACCTTT p.K529Rfs*4 | Frame Shift Del (DEL) | VAF 46/381 reads (12%) | catalogued as COSV64602454; called by pindel, varscan2*
- SEMA4C | c.1975del p.L659Wfs*87 | Frame Shift Del (DEL) | VAF 6/24 reads (25%) | catalogued as rs1436989321; called by mutect2, varscan2
- SENP1 | c.1227del p.G410Vfs*4 | Frame Shift Del (DEL) | VAF 42/101 reads (42%) | catalogued as rs750651342; called by mutect2, varscan2
- SENP7 | c.3068G>A p.R1023H | Missense Mutation (SNP) | VAF 71/159 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750570862, COSV58607948; called by muse, mutect2, varscan2
- SERINC4 | c.1514G>A p.R505H | Missense Mutation (SNP) | VAF 45/131 reads (34%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.081); catalogued as rs754483746, COSV51048647; called by muse, mutect2, varscan2
- SERPINC1 | c.491G>A p.R164Q | Missense Mutation (SNP) | VAF 106/276 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); catalogued as rs483352852, COSV62928863; ClinVar: not provided; called by muse, mutect2, varscan2
- SERPINE2 | c.176C>T p.A59V | Missense Mutation (SNP) | VAF 40/148 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs769638840, COSV51455837; called by muse, mutect2, varscan2
- SETBP1 | c.400A>G p.K134E | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56313496; called by muse, mutect2, varscan2
- SETBP1 | c.2752C>T p.R918W | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as rs757255318, COSV56313515; called by muse, mutect2, varscan2
- SEZ6L2 | c.1991G>A p.R664Q (on ENST00000308713 / NM_001114099.3; = p.R594Q on NM_012410.4) | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as rs777811483, COSV58097323; called by muse, mutect2, varscan2
- SFI1 | c.1276C>T p.R426W (on ENST00000400288 / NM_001007467.3; = p.R395W on NM_014775.4) | Missense Mutation (SNP) | VAF 64/408 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs762410102, COSV66289742; called by muse, mutect2, varscan2
- SFXN2 | c.665C>T p.A222V | Missense Mutation (SNP) | VAF 48/140 reads (34%) | SIFT tolerated (0.79); PolyPhen benign (0.013); catalogued as COSV64011817; called by muse, mutect2, varscan2
- SIGLEC6 | c.848A>G p.H283R | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV58432010; called by muse, mutect2, varscan2
- SIGLEC9 | c.557C>T p.S186F | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.127); catalogued as rs764072934, COSV51582602, COSV51583355; called by muse, mutect2
- SIN3A | c.3633G>T p.Q1211H | Missense Mutation (SNP) | VAF 97/235 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs935934765, COSV51226522; called by muse, mutect2, varscan2
- SIPA1L1 | c.4435G>A p.A1479T | Missense Mutation (SNP) | VAF 103/242 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs1489958715, COSV62168462; called by muse, mutect2, varscan2
- SIRPB1 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 15/416 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.063); catalogued as COSV53537514; called by muse, mutect2
- SIX2 | c.331G>A p.V111M | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV57390076; called by muse, mutect2, varscan2
- SKI | c.1124G>A p.R375H | Missense Mutation (SNP) | VAF 145/356 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs762209697, COSV66012936; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC13A1 | c.604G>C p.V202L | Missense Mutation (SNP) | VAF 9/135 reads (7%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as rs1290852653, COSV52008235; called by muse, mutect2
- SLC13A2 | c.328G>A p.A110T | Missense Mutation (SNP) | VAF 42/144 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781999580, COSV58992636; called by muse, mutect2
741 further variants in this file (393 protein-altering or splice-affecting, 312 silent, 36 other) are not listed here.
